Somatic mutation profile of tumor specimen HCM-CSHL-0174-C22-86A (aliquot HCM-CSHL-0174-C22-86A-01D-A85C-36) from HCMI case HCM-CSHL-0174-C22, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage IIIB; Tumor grade: GX; Age at diagnosis: 64.9 years (23,717 days).
Specimen HCM-CSHL-0174-C22-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 14.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 407025ac-d447-4285-b7d9-cbf2e0d2d4a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0174-C22-10A (Blood Derived Normal), aliquot HCM-CSHL-0174-C22-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5832d20f-e28d-43a4-ac73-dd426534381f

The open-access MAF lists 1,843 somatic variants for this specimen: 1,297 protein-altering or splice-affecting, 371 silent, 175 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 936, Silent 371, Frame Shift Del 220, Intron 91, Frame Shift Ins 44, Nonsense Mutation 39, 5'UTR 32, Splice Site 29, 3'UTR 28, RNA 16, In Frame Del 15, Splice Region 10.

Variants (750 of 1,843; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.4615G>A p.E1539K (on ENST00000272895 / NM_173076.3; = p.E1221K on NM_015657.3) | Missense Mutation (SNP) | VAF 270/375 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28940271, CM032168, COSV55968759; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AR | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 248/564 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs104894742, CM960074; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AR | c.2324G>A p.R775H | Missense Mutation (SNP) | VAF 255/517 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs137852572, CM136027, CM920086, COSV65954067; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRCA1 | c.1961del p.K654Sfs*47 | Frame Shift Del (DEL) | VAF 188/448 reads (42%) | catalogued as rs80357522, CD076746, CD951610; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- DYRK1A | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 247/550 reads (45%) | catalogued as rs724159949, CM1413207, COSV58294256; ClinVar: pathogenic; called by muse, varscan2
- DYSF | c.4200del p.I1401Sfs*47 | Frame Shift Del (DEL) | VAF 114/431 reads (26%) | catalogued as rs398123786, CM053841; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GJA1 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 254/500 reads (51%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.768); catalogued as rs2227885, CM014191; ClinVar: likely benign / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- HIVEP2 | c.2827C>T p.R943* | Nonsense Mutation (SNP) | VAF 110/836 reads (13%) | catalogued as rs869312841, CM163425, COSV50014693; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNT1 | c.2743G>A p.A915T (on ENST00000488444; = p.A934T on NM_020822.3) | Missense Mutation (SNP) | VAF 123/398 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs397515403, CM129794, COSV53703025, COSV99706966; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MEN1 | c.1561del p.R521Gfs*43 | Frame Shift Del (DEL) | VAF 386/497 reads (78%) | catalogued as rs767319284, CD972318, CM080439, COSV53644931; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- OTC | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 199/464 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs72554307, CM950870; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 270/592 reads (46%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 111/263 reads (42%) | catalogued as rs121913289; ClinVar: pathogenic; called by pindel, varscan2
- SDHA | c.1526C>T p.S509L | Missense Mutation (SNP) | VAF 172/390 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.218); catalogued as rs397514541, CM163827, COSV53767867, COSV53772354; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- SMAD4 | c.692dup p.S232Qfs*3 | Frame Shift Ins (INS) | VAF 152/184 reads (83%) | catalogued as rs377767334, COSV61691229; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.755T>C p.L252P | Missense Mutation (SNP) | VAF 407/407 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912653, CM900212, COSV52764738, COSV52950153; ClinVar: pathogenic; called by muse, mutect2, varscan2
- WRN | c.3382del p.S1128Vfs*34 | Frame Shift Del (DEL) | VAF 64/180 reads (36%) | catalogued as rs778872619; ClinVar: pathogenic; called by pindel, varscan2
- ABCA4 | c.6365C>T p.A2122V | Missense Mutation (SNP) | VAF 282/620 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV64671076, COSV64676839; called by muse, mutect2, varscan2
- ABCC10 | c.3835G>A p.V1279M (on ENST00000372530 / NM_001198934.2; = p.V1251M on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 266/624 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs762311029; called by muse, varscan2
- ABCC9 | c.3131G>T p.G1044V | Missense Mutation (SNP) | VAF 80/516 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.044); catalogued as COSV53965917; called by muse, varscan2
- ABL1 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 356/358 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1191034511, COSV59325948; called by muse, varscan2
- ABLIM3 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 222/746 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as rs747716272, COSV58641823; called by muse, varscan2
- AC008763.3 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 531/1144 reads (46%) | catalogued as rs1461187623, COSV100365374; called by muse, mutect2, varscan2
- ACACA | c.5933G>A p.R1978H | Missense Mutation (SNP) | VAF 158/345 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs774579864; called by muse, mutect2, varscan2
- ACAN | c.5390G>A p.G1797E | Missense Mutation (SNP) | VAF 511/755 reads (68%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV100719024; called by muse, mutect2, varscan2
- ACAP2 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 29/425 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.107); catalogued as COSV58753631; called by muse, mutect2
- ADAMTS17 | c.3127G>A p.A1043T | Missense Mutation (SNP) | VAF 183/630 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as rs993859963; called by muse, mutect2, varscan2
- ADAMTS6 | c.2252C>T p.A751V | Missense Mutation (SNP) | VAF 104/299 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.41); catalogued as rs143194045; called by muse, mutect2, varscan2
- ADCY1 | c.2536G>A p.A846T | Missense Mutation (SNP) | VAF 319/539 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1338700641, COSV52040140; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 156/273 reads (57%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRB3 | c.1186C>G p.L396V | Missense Mutation (SNP) | VAF 78/404 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.1); catalogued as rs371587255, COSV65393454; called by muse, varscan2
- ADGRE1 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 210/442 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs753846792; called by muse, varscan2
- ADGRL1 | c.3419G>A p.R1140H (on ENST00000340736 / NM_001008701.3; = p.R1135H on NM_014921.5) | Missense Mutation (SNP) | VAF 250/486 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as rs776587952; called by muse, mutect2, varscan2
- ADGRV1 | c.5944dup p.S1982Ffs*2 | Frame Shift Ins (INS) | VAF 75/255 reads (29%) | catalogued as rs1554081619; called by mutect2, pindel, varscan2
- AFF2 | c.2513A>G p.Q838R | Missense Mutation (SNP) | VAF 447/975 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.339); catalogued as rs1557287421; called by muse, mutect2, varscan2
- AFF2 | c.3110G>A p.S1037N | Missense Mutation (SNP) | VAF 353/730 reads (48%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.764); catalogued as COSV53979732; called by mutect2, varscan2
- AFF3 | c.815C>A p.P272Q | Missense Mutation (SNP) | VAF 394/611 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV57865960; called by muse, mutect2, varscan2
- AFP | c.1043del p.N348Ifs*22 | Frame Shift Del (DEL) | VAF 28/166 reads (17%) | catalogued as rs779815391; called by pindel, varscan2
- AGBL1 | c.2330C>T p.T777M | Missense Mutation (SNP) | VAF 146/564 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376945285; called by muse, varscan2
- AGGF1 | c.1696C>T p.R566* | Nonsense Mutation (SNP) | VAF 110/328 reads (34%) | catalogued as rs758213462, COSV57227705; called by muse, varscan2
- AGO1 | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 207/330 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1385910631, COSV64594759; called by muse, mutect2, varscan2
- AICDA | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 233/560 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.92); catalogued as rs373061990, COSV57563722, COSV57563879; called by muse, mutect2
- AL031777.2 | c.222_224del p.N74del | In Frame Del (DEL) | VAF 188/392 reads (48%) | catalogued as rs773584959; called by pindel, varscan2
- ALDH16A1 | c.646del p.E216Sfs*9 | Frame Shift Del (DEL) | VAF 104/692 reads (15%) | catalogued as rs1201603395, COSV53193168; called by mutect2, pindel, varscan2
- ALG10 | c.981dup p.V328Cfs*18 | Frame Shift Ins (INS) | VAF 197/445 reads (44%) | catalogued as rs768493124; called by mutect2, pindel, varscan2
- AMPD2 | c.2029G>A p.A677T | Missense Mutation (SNP) | VAF 257/764 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV56648847; called by muse, mutect2, varscan2
- ANKRD24 | c.2602C>T p.R868C | Missense Mutation (SNP) | VAF 259/1439 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs1342357921; called by muse, mutect2, varscan2
- ANKRD31 | c.5368A>G p.N1790D | Missense Mutation (SNP) | VAF 85/342 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs963721806; called by muse, mutect2, varscan2
- ANO1 | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 352/352 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV60290126; called by muse, varscan2
- ANO3 | c.2044-1G>A p.X682_splice | Splice Site (SNP) | VAF 105/324 reads (32%) | catalogued as rs1171029662; called by muse, mutect2, varscan2
- AP1M1 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 148/689 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as rs200460904, COSV52225294; called by muse, varscan2
- AP4E1 | c.1064del p.L355* | Frame Shift Del (DEL) | VAF 108/210 reads (51%) | catalogued as rs1357583521; called by pindel, varscan2
- APBB1 | c.1763C>T p.A588V | Missense Mutation (SNP) | VAF 155/543 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1420119374; called by muse, mutect2, varscan2
- APOE | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 681/1381 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as CM111115, COSV52985125; called by muse, mutect2, varscan2
- APOOL | c.595del p.T199Lfs*3 | Frame Shift Del (DEL) | VAF 117/277 reads (42%) | catalogued as rs1293508812; called by mutect2, pindel, varscan2
- AQR | c.2291C>T p.A764V | Missense Mutation (SNP) | VAF 275/461 reads (60%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs780179363, COSV99333261; called by muse, mutect2, varscan2
- ARAP1 | c.1514G>A p.R505H (on ENST00000393609 / NM_001040118.2; = p.R260H on NM_015242.4) | Missense Mutation (SNP) | VAF 384/385 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs777692919; called by muse, varscan2
- ARHGAP21 | c.2939C>T p.T980M | Missense Mutation (SNP) | VAF 274/552 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs530533376, COSV57604133; called by muse, varscan2
- ARHGEF10L | c.432C>T p.P144= | Splice Region (SNP) | VAF 223/390 reads (57%) | catalogued as rs755364404, COSV63422614; called by muse, mutect2, varscan2
- ARID1A | c.2402del p.G801Vfs*32 | Frame Shift Del (DEL) | VAF 168/325 reads (52%) | catalogued as COSV61388445; called by mutect2, pindel, varscan2
- ARID1A | c.3820G>T p.G1274* | Nonsense Mutation (SNP) | VAF 234/803 reads (29%) | catalogued as COSV61371474; called by muse, mutect2, varscan2
- ARRB2 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 477/477 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.318); catalogued as COSV52617001; called by mutect2, varscan2
- ARSD | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 700/1472 reads (48%) | SIFT tolerated (0.59); PolyPhen benign (0.42); catalogued as rs774734859; called by muse, varscan2
- ARSI | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 142/546 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60817065, COSV60817994; called by muse, mutect2, varscan2
- ASB11 | c.68dup p.F24Lfs*2 | Frame Shift Ins (INS) | VAF 116/344 reads (34%) | catalogued as rs770804405; called by mutect2, varscan2
- ASTN1 | c.2540C>T p.A847V | Missense Mutation (SNP) | VAF 285/596 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as rs745514951, COSV56065176, COSV56066780; called by muse, varscan2
- ASTN1 | c.2108C>T p.T703M | Missense Mutation (SNP) | VAF 290/596 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs774847597, COSV99920531; called by muse, varscan2
- ASXL2 | c.1841G>A p.R614Q | Missense Mutation (SNP) | VAF 84/324 reads (26%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.946); catalogued as rs1307171996; called by muse, mutect2, varscan2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 438/990 reads (44%) | catalogued as rs768611141; called by mutect2, pindel, varscan2
- ATG16L1 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 28/606 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs765452525, COSV104417253; called by muse, mutect2
- ATP10A | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 67/327 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.082); catalogued as rs199711038, COSV63518494; called by muse, mutect2, varscan2
- ATP2A1 | c.2267_2269del p.N756del | In Frame Del (DEL) | VAF 232/530 reads (44%) | catalogued as rs766141393; called by pindel, varscan2
- ATP4A | c.1292C>A p.A431E | Missense Mutation (SNP) | VAF 437/910 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as rs375401694; called by muse, mutect2, varscan2
- B9D2 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 148/821 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs572237537; called by muse, mutect2, varscan2
- BAG4 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 263/483 reads (54%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.707); catalogued as rs770041398, COSV54861341, COSV54862630; called by muse, mutect2, varscan2
- BAIAP3 | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 288/600 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.135); catalogued as rs770815658; called by muse, mutect2, varscan2
- BAZ1B | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 202/448 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59991019, COSV59993745; called by muse, varscan2
- BCL6 | c.1184C>A p.P395H | Missense Mutation (SNP) | VAF 423/741 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as rs1178677766, COSV99216165; called by muse, mutect2, varscan2
- BCL7C | c.617del p.P206Hfs*36 | Frame Shift Del (DEL) | VAF 301/749 reads (40%) | catalogued as rs754078059; called by mutect2, pindel, varscan2
- BCL9L | c.1346del p.P449Lfs*14 | Frame Shift Del (DEL) | VAF 48/311 reads (15%) | catalogued as rs754310793, COSV52681762; called by mutect2, pindel, varscan2
- BCR | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 403/1099 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as rs1244976763; called by muse, mutect2, varscan2
- BEND3 | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 426/427 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs147116683; called by muse, mutect2, varscan2
- BMS1 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 299/504 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs748277670; called by muse, mutect2, varscan2
- BTK | c.215del p.N72Ifs*49 | Frame Shift Del (DEL) | VAF 185/449 reads (41%) | catalogued as CD087030, CD982512, CX984150; called by pindel, varscan2
- C11orf52 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 132/704 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs144473843; called by muse, varscan2
- C16orf46 | c.412del p.Q138Rfs*66 | Frame Shift Del (DEL) | VAF 310/721 reads (43%) | catalogued as rs1567574033; called by mutect2, pindel, varscan2
- C1QTNF2 | c.218G>A p.R73Q (on ENST00000393975; = p.R28Q on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 270/965 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs375483575; called by muse, mutect2, varscan2
- C21orf58 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 563/1136 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs375276205; called by muse, mutect2, varscan2
- C2CD5 | c.1090G>A p.V364I | Missense Mutation (SNP) | VAF 236/494 reads (48%) | SIFT tolerated (0.79); PolyPhen benign (0.073); catalogued as rs151297499; called by muse, mutect2, varscan2
- C3orf33 | c.820A>G p.N274D (on ENST00000340171 / NM_001308229.2; = p.N231D on NM_173657.2) | Missense Mutation (SNP) | VAF 71/502 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV100420115; called by muse, mutect2
- CACNA1E | c.2705del p.G902Efs*5 | Frame Shift Del (DEL) | VAF 207/542 reads (38%) | catalogued as COSV62382319; called by mutect2, pindel, varscan2
- CAGE1 | c.2238del p.A747Pfs*9 (on ENST00000512086; = p.A611Pfs*9 on NM_205864.3) | Frame Shift Del (DEL) | VAF 129/245 reads (53%) | catalogued as COSV57081154; called by mutect2, pindel, varscan2
- CAMK1G | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 206/446 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs763192311; called by muse, mutect2, varscan2
- CAMSAP3 | c.2246C>T p.T749M | Missense Mutation (SNP) | VAF 626/1314 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.247); catalogued as rs185048709; called by muse, mutect2, varscan2
- CAPG | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 221/601 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.127); catalogued as rs756006551, COSV99809333; called by muse, mutect2, varscan2
- CARM1 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 409/878 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV53404227; called by muse, mutect2, varscan2
- CARMIL1 | c.3244C>T p.R1082* | Nonsense Mutation (SNP) | VAF 333/541 reads (62%) | catalogued as rs1385108756, COSV61523112; called by muse, mutect2, varscan2
- CASKIN2 | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 128/854 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58690238; called by muse, varscan2
- CBARP | c.1067G>T p.R356L (on ENST00000382477; = p.R336L on NM_152769.3) | Missense Mutation (SNP) | VAF 465/948 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53071806; called by muse, mutect2, varscan2
- CCDC136 | c.2066A>G p.Q689R | Missense Mutation (SNP) | VAF 208/432 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV99923222; called by muse, mutect2, varscan2
- CCDC168 | c.8926G>A p.A2976T | Missense Mutation (SNP) | VAF 173/480 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as COSV59426418; called by muse, mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 260/587 reads (44%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC38 | c.355A>G p.R119G | Missense Mutation (SNP) | VAF 236/501 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs145671956; called by muse, mutect2, varscan2
- CCDC92 | c.801del p.I268Sfs*40 | Frame Shift Del (DEL) | VAF 214/1140 reads (19%) | catalogued as rs773752200; called by mutect2, varscan2
- CCN4 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 292/899 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs778202911, COSV51533217; called by muse, mutect2, varscan2
- CCNJ | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 176/487 reads (36%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.991); catalogued as rs1488931381, COSV99796155; called by muse, mutect2
- CCSAP | c.576del p.K192Nfs*58 | Frame Shift Del (DEL) | VAF 121/607 reads (20%) | catalogued as rs778010925; called by mutect2, pindel, varscan2
- CCSER1 | c.2464C>T p.R822W | Missense Mutation (SNP) | VAF 106/423 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs1327494584, COSV61411301; called by muse, mutect2, varscan2
- CCT7 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 117/396 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as rs11544996; called by muse, mutect2, varscan2
- CD38 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 159/716 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1447909044; called by muse, mutect2, varscan2
- CD3E | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 328/707 reads (46%) | SIFT tolerated (0.8); PolyPhen benign (0.123); catalogued as rs200087808; ClinVar: uncertain significance; called by muse, varscan2
- CD3E | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 307/630 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs563868055, COSV62346096; called by muse, mutect2, varscan2
- CD93 | c.1307del p.G436Afs*152 | Frame Shift Del (DEL) | VAF 399/939 reads (42%) | catalogued as rs779465056; called by mutect2, pindel, varscan2
- CDADC1 | c.1534G>A p.G512R | Missense Mutation (SNP) | VAF 120/347 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.181); catalogued as rs149569821; called by muse, mutect2, varscan2
- CDC45 | c.326T>C p.V109A | Missense Mutation (SNP) | VAF 67/631 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV54243188; called by muse, varscan2
- CDH22 | c.1240G>A p.G414S | Missense Mutation (SNP) | VAF 542/961 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as rs1303483268, COSV64837485; called by muse, mutect2, varscan2
- CDK13 | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 186/319 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs934764468, COSV51706512; called by muse, mutect2, varscan2
- CDYL | c.1192G>A p.V398I (on ENST00000328908 / NM_001368125.1; = p.V344I on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 379/652 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs761722419, COSV59361810; called by muse, varscan2
- CELSR1 | c.4271G>A p.G1424D | Missense Mutation (SNP) | VAF 42/1340 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1260381700; called by muse, mutect2
- CELSR2 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 167/803 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs565549939; called by muse, mutect2, varscan2
- CEP97 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 265/596 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs145086802; called by muse, mutect2, varscan2
- CERS6 | c.118C>A p.L40I | Missense Mutation (SNP) | VAF 370/588 reads (63%) | SIFT tolerated (0.32); PolyPhen benign (0.035); catalogued as COSV59830504; called by muse, varscan2
- CES5A | c.1005T>G p.I335M | Missense Mutation (SNP) | VAF 401/825 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs866504798; called by muse, mutect2, varscan2
- CFAP43 | c.4579dup p.S1527Ffs*10 | Frame Shift Ins (INS) | VAF 120/239 reads (50%) | catalogued as rs775645707; called by mutect2, varscan2
- CFAP94 | c.1798G>A p.A600T (on ENST00000320267 / NM_001352064.2; = p.A606T on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 289/583 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57230325; called by muse, varscan2
- CGB5 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 155/937 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1201663825; called by muse, mutect2, varscan2
- CHAD | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 137/922 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as rs1318689346, COSV51970789; called by muse, mutect2, varscan2
- CHD5 | c.5660del p.P1887Rfs*14 | Frame Shift Del (DEL) | VAF 218/616 reads (35%) | catalogued as rs928253921; called by mutect2, varscan2
- CHPF | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 321/492 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as rs776863694, COSV60537310; called by muse, mutect2, varscan2
- CHRM4 | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 399/848 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs759941649, COSV63126375; called by muse, mutect2, varscan2
- CHRNA6 | c.494del p.F165Sfs*10 | Frame Shift Del (DEL) | VAF 202/416 reads (49%) | catalogued as rs774808608; called by mutect2, pindel, varscan2
- CLASP2 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 322/323 reads (100%) | SIFT tolerated (0.24); PolyPhen benign (0.114); catalogued as rs368159421; called by muse, mutect2, varscan2
- CLEC16A | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 288/608 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.065); catalogued as rs866629699; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 98/261 reads (38%) | catalogued as rs369752219; called by mutect2, varscan2
- CMIP | c.1555C>G p.R519G (on ENST00000537098 / NM_198390.2; = p.R425G on NM_030629.3) | Missense Mutation (SNP) | VAF 400/833 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV67698609; called by muse, mutect2, varscan2
- CNGA2 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 408/867 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756195328, COSV100323969; called by muse, mutect2, varscan2
- CNNM1 | c.2176+1G>A p.X726_splice | Splice Site (SNP) | VAF 352/587 reads (60%) | catalogued as rs376631525; called by muse, varscan2
- COL20A1 | c.2641G>A p.A881T | Missense Mutation (SNP) | VAF 212/593 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.129); catalogued as rs748113437, COSV58914315; called by muse, mutect2, varscan2
- COL6A3 | c.2306C>T p.A769V | Missense Mutation (SNP) | VAF 328/497 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as rs753966526, COSV55104699; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL8A1 | c.2183C>T p.A728V | Missense Mutation (SNP) | VAF 330/670 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV53731656; called by muse, varscan2
- COL8A2 | c.1553C>T p.T518M | Missense Mutation (SNP) | VAF 165/816 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.243); catalogued as rs781002025, COSV100291451; called by muse, mutect2, varscan2
- COL9A3 | c.1548+8G>A | Splice Region (SNP) | VAF 138/635 reads (22%) | catalogued as rs376918493; called by muse, varscan2
- CORO6 | c.1194del p.K399Sfs*96 | Frame Shift Del (DEL) | VAF 381/905 reads (42%) | catalogued as rs756429595; called by mutect2, pindel, varscan2
- CPT1A | c.637C>T p.L213F | Missense Mutation (SNP) | VAF 87/646 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV55761441; called by muse, mutect2, varscan2
- CRNKL1 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 185/185 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs781077783, COSV99842955; called by muse, mutect2, varscan2
- CSMD1 | c.9308C>T p.P3103L (on ENST00000520002; = p.P3102L on NM_033225.6) | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs984147998, COSV59277615; called by muse, mutect2
- CSPP1 | c.1102C>T p.P368S (on ENST00000676605; = p.P327S on NM_024790.6) | Missense Mutation (SNP) | VAF 151/284 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.143); catalogued as COSV51580378; called by muse, mutect2, varscan2
- CT47B1 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 390/837 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs746190277, COSV100989010; called by muse, mutect2, varscan2
- CTBP1 | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 163/502 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1388198458; called by muse, mutect2, varscan2
- CTNNA1 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 453/456 reads (99%) | catalogued as COSV57077911; called by muse, mutect2, varscan2
- CWH43 | c.337T>C p.S113P | Missense Mutation (SNP) | VAF 204/378 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as rs1415857655, COSV99893165; called by muse, varscan2
- CYP2C8 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 223/544 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs1313975039; called by muse, mutect2, varscan2
- CYP2C9 | c.790A>G p.I264V | Missense Mutation (SNP) | VAF 158/314 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.37); catalogued as COSV53247604; called by muse, mutect2, varscan2
- CYS1 | c.475T>G p.*159Gext*29 | Nonstop Mutation (SNP) | VAF 205/557 reads (37%) | catalogued as rs774180325; called by muse, varscan2
- CYTIP | c.1037C>A p.P346H | Missense Mutation (SNP) | VAF 96/295 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99938969; called by muse, mutect2, varscan2
- DCBLD1 | c.1865G>A p.R622H | Missense Mutation (SNP) | VAF 215/1268 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1422985420, COSV51645774; called by muse, mutect2, varscan2
- DENND1B | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 302/660 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs779126393; called by muse, varscan2
- DEPDC5 | c.2968G>A p.A990T (on ENST00000400246; = p.A1059T on NM_014662.5) | Missense Mutation (SNP) | VAF 480/860 reads (56%) | SIFT tolerated (0.54); PolyPhen benign (0.153); catalogued as rs763158282, COSV99835501; called by muse, mutect2, varscan2
- DGKK | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 59/1452 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs782206353, COSV101052905; called by muse, mutect2
- DICER1 | c.3791C>T p.T1264M | Missense Mutation (SNP) | VAF 122/539 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs139346443; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DIP2A | c.3706G>A p.V1236I | Missense Mutation (SNP) | VAF 369/825 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.061); catalogued as rs761203268, COSV59481294; called by muse, mutect2, varscan2
- DIP2C | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 328/524 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.292); catalogued as rs775934914, COSV99792008; called by muse, mutect2, varscan2
- DLG2 | c.1390G>T p.G464* | Nonsense Mutation (SNP) | VAF 76/400 reads (19%) | catalogued as COSV54662150; called by muse, mutect2, varscan2
- DLL4 | c.2053G>A p.V685I | Missense Mutation (SNP) | VAF 232/558 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1404800749, COSV99990087; called by muse, varscan2
- DLST | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 224/516 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1025995190, COSV53168045; called by muse, varscan2
- DNAH10 | c.3172C>T p.R1058* (on ENST00000409039; = p.R997* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 295/615 reads (48%) | catalogued as rs1449530904, COSV68991805; called by muse, mutect2, varscan2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 26/92 reads (28%) | catalogued as rs751671358; called by mutect2, varscan2
- DNAH5 | c.4559T>C p.M1520T | Missense Mutation (SNP) | VAF 70/484 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as rs916516633, COSV54247518; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJC10 | c.2314G>A p.A772T | Missense Mutation (SNP) | VAF 194/340 reads (57%) | SIFT tolerated (0.3); PolyPhen benign (0.07); catalogued as rs768125706; called by muse, mutect2, varscan2
- DNHD1 | c.10298G>A p.R3433H | Missense Mutation (SNP) | VAF 217/334 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1182015408; called by muse, mutect2, varscan2
- DOCK8 | c.5059G>A p.V1687M | Missense Mutation (SNP) | VAF 281/282 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as rs767895149, COSV101209866; called by muse, varscan2
- DOCK9 | c.3526G>A p.V1176I (on ENST00000376460 / NM_001366676.2; = p.V1177I on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 210/570 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0.036); catalogued as rs1471236386, COSV59643438; called by muse, mutect2, varscan2
- DOT1L | c.3851C>T p.A1284V | Missense Mutation (SNP) | VAF 249/1365 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV67112722; called by muse, mutect2, varscan2
- DPF2 | c.112C>A p.R38S | Missense Mutation (SNP) | VAF 338/752 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV52891484; called by muse, mutect2, varscan2
- DR1 | c.516T>A p.D172E | Missense Mutation (SNP) | VAF 94/472 reads (20%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV64725888; called by muse, mutect2, varscan2
- DSCAML1 | c.754G>A p.A252T (on ENST00000321322; = p.A192T on NM_020693.4) | Missense Mutation (SNP) | VAF 345/769 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs142110596, COSV58389573; called by muse, mutect2, varscan2
- DVL1 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 295/681 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs149964617; called by muse, mutect2, varscan2
- E2F1 | c.1303del p.L435Wfs*58 | Frame Shift Del (DEL) | VAF 199/424 reads (47%) | catalogued as rs1409099723, COSV55776265; called by mutect2, pindel, varscan2
- ECT2 | c.2507del p.K836Rfs*21 (on ENST00000392692 / NM_001349098.2; = p.K805Rfs*21 on NM_018098.6 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 126/263 reads (48%) | catalogued as rs1560030630; called by pindel, varscan2
- EIF3CL | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 278/616 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.898); catalogued as COSV66534056; called by muse, varscan2
- EIF4A3 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 167/364 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as rs755596816; called by muse, mutect2, varscan2
- EML4 | c.387del p.E130Rfs*43 | Frame Shift Del (DEL) | VAF 104/320 reads (33%) | catalogued as rs770453803; called by mutect2, varscan2
- EP400 | c.6545C>T p.A2182V | Missense Mutation (SNP) | VAF 441/894 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.161); catalogued as rs565827189; called by muse, varscan2
- EPRS1 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 203/440 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1448727059; called by muse, mutect2, varscan2
- ERBIN | c.3389G>A p.R1130Q | Missense Mutation (SNP) | VAF 208/525 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs144581883; called by muse, varscan2
- ERICH3 | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 282/491 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs865943394, COSV58604950; called by muse, mutect2, varscan2
- FAF2 | c.484-1G>T p.X162_splice | Splice Site (SNP) | VAF 88/325 reads (27%) | catalogued as COSV99990456; called by muse, mutect2, varscan2
- FAM149A | c.2095C>T p.R699* (on ENST00000356371 / NM_001367768.2; = p.R408* on NM_015398.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 98/393 reads (25%) | catalogued as rs766661467, COSV57030946; called by muse, mutect2, varscan2
- FAM184A | c.2854C>T p.R952W | Missense Mutation (SNP) | VAF 286/562 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs775749960; called by muse, mutect2, varscan2
- FAM3D | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 318/319 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs368973392; called by muse, mutect2, varscan2
- FAM83D | c.1483G>A p.A495T | Missense Mutation (SNP) | VAF 334/821 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757902095; called by muse, mutect2, varscan2
- FAM91A1 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 382/544 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs1012721253, COSV58236363; called by muse, mutect2, varscan2
- FAR2 | c.529del p.I177Sfs*8 | Frame Shift Del (DEL) | VAF 178/478 reads (37%) | catalogued as rs757443519; called by mutect2, varscan2
- FASN | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 422/924 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as rs1009899437; called by muse, mutect2, varscan2
- FASTKD1 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 100/305 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs149861551; called by muse, mutect2, varscan2
- FAT4 | c.14389C>T p.L4797F | Missense Mutation (SNP) | VAF 148/444 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs267600018, COSV58703970; called by muse, mutect2, varscan2
- FBN3 | c.4039T>C p.C1347R | Missense Mutation (SNP) | VAF 247/624 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769762222, COSV54467441; called by muse, mutect2
- FBRSL1 | c.876del p.A293Pfs*121 | Frame Shift Del (DEL) | VAF 131/918 reads (14%) | catalogued as rs1461432773; called by mutect2, pindel, varscan2
- FBXW10 | c.86G>A p.C29Y | Missense Mutation (SNP) | VAF 238/491 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs748140429; called by muse, mutect2, varscan2
- FGD2 | c.1444C>T p.R482W | Missense Mutation (SNP) | VAF 391/819 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780657307, COSV51464056; called by muse, varscan2
- FILIP1L | c.2247del p.K749Nfs*2 (on ENST00000354552 / NM_182909.3; = p.K509Nfs*2 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 260/582 reads (45%) | catalogued as COSV58769165; called by mutect2, varscan2
- FKBP9 | c.384del p.N129Ifs*10 | Frame Shift Del (DEL) | VAF 92/267 reads (34%) | catalogued as rs752076602; called by mutect2, pindel, varscan2
- FKRP | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 604/1328 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764621521; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNA | c.2836G>T p.G946C | Missense Mutation (SNP) | VAF 266/593 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV61051609; called by muse, mutect2, varscan2
- FLNC | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 383/805 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1417082178, COSV57949813; called by muse, mutect2, varscan2
- FLOT2 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 248/538 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774018833; called by muse, mutect2, varscan2
- FLT3 | c.2729A>G p.Q910R | Missense Mutation (SNP) | VAF 140/382 reads (37%) | SIFT tolerated (0.89); PolyPhen benign (0.021); catalogued as rs1318196723; called by muse, mutect2, varscan2
- FLT4 | c.2228C>T p.A743V | Missense Mutation (SNP) | VAF 194/1254 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV56098861; called by muse, varscan2
- FLYWCH1 | c.1907G>A p.R636Q (on ENST00000253928 / NM_001308068.2; = p.R635Q on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 401/870 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs777293183; called by muse, mutect2, varscan2
- FNIP2 | c.2686G>A p.A896T | Missense Mutation (SNP) | VAF 169/527 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1314321471, COSV52439130; called by muse, mutect2, varscan2
- FOLH1 | c.1501del p.S501Vfs*12 | Frame Shift Del (DEL) | VAF 44/278 reads (16%) | catalogued as rs764290022, COSV57049642; called by pindel, varscan2
- FOXC1 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 468/835 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057519473; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXH1 | c.937del p.V313Wfs*15 | Frame Shift Del (DEL) | VAF 246/1118 reads (22%) | catalogued as COSV56761013; called by mutect2, pindel, varscan2
- FRZB | c.855del p.V286Lfs*6 | Frame Shift Del (DEL) | VAF 164/281 reads (58%) | catalogued as rs1366062663; called by mutect2, pindel, varscan2
- G6PD | c.1180G>A p.V394M | Missense Mutation (SNP) | VAF 703/1446 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as CM920286, COSV63703327; called by muse, mutect2, varscan2
- GABPB2 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 121/775 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770162643, COSV104425990; called by muse, mutect2, varscan2
- GALC | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 105/723 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs938939224; called by muse, mutect2, varscan2
- GALNT3 | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 108/218 reads (50%) | catalogued as rs376963628; called by muse, varscan2
- GGTLC1 | c.332C>A p.P111Q | Missense Mutation (SNP) | VAF 594/1217 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs541165436, COSV99600652; called by muse, mutect2, varscan2
- GIGYF1 | c.331dup p.L111Pfs*20 | Frame Shift Ins (INS) | VAF 308/670 reads (46%) | catalogued as rs763147690; called by mutect2, varscan2
- GIT1 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 392/825 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs769808064; called by muse, mutect2, varscan2
- GNB3 | c.304A>G p.T102A | Missense Mutation (SNP) | VAF 385/775 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.024); catalogued as COSV51831647; called by muse, mutect2, varscan2
- GNE | c.623G>A p.R208H (on ENST00000396594 / NM_001128227.3; = p.R177H on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 353/355 reads (99%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs772597073, COSV64951377; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- GNPAT | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 198/505 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs767959114, COSV64152975; called by muse, mutect2, varscan2
- GP5 | c.1403del p.G468Vfs*43 | Frame Shift Del (DEL) | VAF 261/722 reads (36%) | catalogued as rs750921214; called by mutect2, pindel, varscan2
- GPKOW | c.1408C>A p.P470T | Missense Mutation (SNP) | VAF 274/593 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.107); catalogued as rs782735883; called by muse, mutect2, varscan2
- GPR108 | c.1018G>A p.A340T (on ENST00000264080 / NM_001080452.1; = p.A98T on NM_020171.2) | Missense Mutation (SNP) | VAF 330/750 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs371747238; called by muse, mutect2, varscan2
- GPR173 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 62/1090 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.244); catalogued as rs1465587752, COSV60238004; called by muse, mutect2
- GPR179 | c.4108G>A p.E1370K (on ENST00000621958; = p.E1369K on NM_001004334.4) | Missense Mutation (SNP) | VAF 528/1179 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs11872089; called by muse, mutect2, varscan2
- GRK2 | c.1547G>A p.R516Q | Missense Mutation (SNP) | VAF 341/715 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as rs752975715; called by muse, mutect2, varscan2
- HAPLN4 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 156/885 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774131618, COSV52269980; called by muse, mutect2, varscan2
- HERC1 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 158/159 reads (99%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs769145958, COSV71250686; called by muse, mutect2, varscan2
- HERC4 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 181/308 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1164946098, COSV53268584; called by muse, mutect2, varscan2
- HIPK2 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 115/705 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776135107, COSV104417641; called by muse, mutect2, varscan2
- HIRA | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 198/587 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54277074; called by muse, mutect2, varscan2
- HIRIP3 | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 374/809 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs139557944; called by muse, mutect2, varscan2
- HIVEP2 | c.4556C>T p.S1519L | Missense Mutation (SNP) | VAF 354/870 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs764073074; called by muse, mutect2, varscan2
- HIVEP2 | c.3082C>T p.R1028* | Nonsense Mutation (SNP) | VAF 441/824 reads (54%) | catalogued as COSV50007394; called by muse, varscan2
- HNF4G | c.224C>T p.A75V (on ENST00000354370 / NM_001330561.2; = p.A122V on NM_004133.5) | Missense Mutation (SNP) | VAF 256/370 reads (69%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.954); catalogued as rs770285159, COSV62972179; called by muse, varscan2
- HRC | c.1269del p.R424Gfs*38 | Frame Shift Del (DEL) | VAF 265/619 reads (43%) | catalogued as COSV53255991; called by mutect2, varscan2
- HSPA1L | c.1314del p.V440Cfs*2 | Frame Shift Del (DEL) | VAF 303/725 reads (42%) | catalogued as COSV65149080; called by mutect2, pindel, varscan2
- HSPG2 | c.8212G>A p.V2738M | Missense Mutation (SNP) | VAF 347/650 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144862631; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HSPG2 | c.1858T>C p.Y620H | Missense Mutation (SNP) | VAF 283/831 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs928196274; called by muse, mutect2, varscan2
- HTR1A | c.1088T>C p.I363T | Missense Mutation (SNP) | VAF 150/699 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1262622336; called by muse, mutect2, varscan2
- IGDCC4 | c.3247G>A p.A1083T | Missense Mutation (SNP) | VAF 403/1025 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV61538419; called by muse, mutect2, varscan2
- IGFBP7 | c.498del p.K167Rfs*13 | Frame Shift Del (DEL) | VAF 138/298 reads (46%) | catalogued as rs765398170; called by pindel, varscan2
- IGHV3-16 | c.105dup p.S36Vfs*15 | Frame Shift Ins (INS) | VAF 706/787 reads (90%) | catalogued as rs782240233; called by mutect2, varscan2
- IGHV4-39 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 612/614 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs587685263; called by muse, varscan2
- IGKV1-17 | c.345T>G p.S115R | Missense Mutation (SNP) | VAF 170/424 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1435944291; called by muse, varscan2
- IL15 | c.317G>A p.S106N | Missense Mutation (SNP) | VAF 77/372 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs750342144; called by muse, mutect2, varscan2
- IMPDH1 | c.608G>A p.S203N (on ENST00000470772 / NM_001142573.2; = p.S289N on NM_000883.4) | Missense Mutation (SNP) | VAF 242/518 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV100118624; called by muse, mutect2, varscan2
- INPPL1 | c.3425G>A p.R1142H | Missense Mutation (SNP) | VAF 706/708 reads (100%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs779810240; called by muse, mutect2, varscan2
- INTS1 | c.3478G>T p.A1160S | Missense Mutation (SNP) | VAF 252/749 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.517); catalogued as COSV101247519; called by muse, mutect2, varscan2
- INTS1 | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 170/514 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV67179428; called by muse, mutect2, varscan2
- INTS8 | c.2954del p.K985Sfs*44 | Frame Shift Del (DEL) | VAF 154/395 reads (39%) | catalogued as rs1352150703; called by mutect2, varscan2
- INVS | c.1837C>T p.R613W | Missense Mutation (SNP) | VAF 333/333 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs529208660; called by muse, mutect2, varscan2
- IQCE | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 488/782 reads (62%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.469); catalogued as rs201141275; called by muse, mutect2, varscan2
- IRF7 | c.212G>A p.R71H (on ENST00000397566; = p.R58H on NM_001572.5) | Missense Mutation (SNP) | VAF 597/913 reads (65%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as rs766334448; called by muse, mutect2, varscan2
- IRGC | c.194C>A p.A65E | Missense Mutation (SNP) | VAF 466/1014 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54983350; called by muse, mutect2, varscan2
- IRS1 | c.1791del p.H598Tfs*38 | Frame Shift Del (DEL) | VAF 368/608 reads (61%) | catalogued as rs761880048; called by mutect2, varscan2
- IRX2 | c.295A>G p.S99G | Missense Mutation (SNP) | VAF 253/479 reads (53%) | SIFT tolerated (0.76); PolyPhen benign (0.019); catalogued as rs796424759; called by muse, mutect2, varscan2
- ISG15 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 376/854 reads (44%) | catalogued as rs200652935; called by muse, mutect2, varscan2
- ISLR2 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 322/1082 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.534); catalogued as rs1198523188; called by muse, varscan2
- ISLR2 | c.1222G>A p.V408I | Missense Mutation (SNP) | VAF 381/1178 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.41); catalogued as COSV62303721; called by muse, varscan2
- ITGAL | c.1825G>A p.V609M | Missense Mutation (SNP) | VAF 197/412 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as rs750373265, COSV63322312; called by muse, mutect2, varscan2
- ITGB7 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 268/268 reads (100%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.652); catalogued as rs1356768179; called by muse, varscan2
- ITIH6 | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 466/980 reads (48%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs750304500, COSV54488247; called by muse, mutect2, varscan2
- JAM3 | c.745dup p.V249Gfs*28 | Frame Shift Ins (INS) | VAF 238/514 reads (46%) | catalogued as rs763250381; called by mutect2, varscan2
- KCNA1 | c.745T>G p.F249V | Missense Mutation (SNP) | VAF 406/881 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM940994; called by muse, varscan2
- KCNG4 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 454/1003 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753628017; called by muse, varscan2
- KCNH3 | c.2423G>A p.R808Q | Missense Mutation (SNP) | VAF 529/529 reads (100%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs201670637; called by muse, mutect2, varscan2
- KCNJ9 | c.226G>C p.G76R | Missense Mutation (SNP) | VAF 180/1056 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63631413; called by muse, varscan2
- KCNK2 | c.817G>A p.V273I (on ENST00000444842 / NM_001017425.3; = p.V258I on NM_014217.4) | Missense Mutation (SNP) | VAF 186/408 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs367815630; called by muse, varscan2
- KCNQ2 | c.1793C>T p.A598V (on ENST00000359125 / NM_172107.4; = p.A570V on NM_004518.6) | Missense Mutation (SNP) | VAF 137/642 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.081); catalogued as rs746079131, COSV60549579; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCTD18 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 158/691 reads (23%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs543025211, COSV63344171; called by muse, mutect2, varscan2
- KCTD18 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 198/589 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1243082924, COSV63344199; called by muse, varscan2
- KCTD21 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 123/278 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs778118017, COSV60741135, COSV60741494, COSV60741878; called by muse, mutect2, varscan2
- KIAA0319L | c.2330G>A p.R777Q | Missense Mutation (SNP) | VAF 254/409 reads (62%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs770305152, COSV57848683; called by muse, mutect2, varscan2
- KIAA1671 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 676/1188 reads (57%) | SIFT tolerated (0.2); PolyPhen benign (0.36); catalogued as rs1271381341; called by muse, mutect2, varscan2
- KIAA2026 | c.4717G>A p.V1573M | Missense Mutation (SNP) | VAF 268/269 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101198947; called by muse, mutect2, varscan2
- KIF18B | c.1178del p.G393Efs*91 (on ENST00000593135 / NM_001265577.2; = p.G393Efs*103 on NM_001264573.2) | Frame Shift Del (DEL) | VAF 199/469 reads (42%) | catalogued as rs1347932473, COSV59271974, COSV59272099; called by mutect2, pindel, varscan2
- KIF1A | c.2344del p.R782Afs*30 | Frame Shift Del (DEL) | VAF 407/734 reads (55%) | catalogued as COSV57494105, COSV57504132; called by mutect2, pindel, varscan2
- KIF2B | c.1370C>T p.T457I | Missense Mutation (SNP) | VAF 168/575 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); catalogued as rs528697656, COSV52130072; called by muse, mutect2, varscan2
- KIRREL2 | c.1953del p.C652Afs*79 | Frame Shift Del (DEL) | VAF 340/860 reads (40%) | catalogued as rs761116739, COSV52880030; called by pindel, varscan2
- KLF1 | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 714/1420 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.056); catalogued as rs886054237; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLHL20 | c.1631G>A p.R544H | Missense Mutation (SNP) | VAF 164/348 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1337434730, COSV52940996; called by muse, varscan2
- KLHL22 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 234/658 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1273833949, COSV61020365; called by muse, varscan2
- KLHL40 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 334/334 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs187688307, COSV99825551; called by muse, mutect2, varscan2
- KLRK1 | c.164del p.F55Sfs*7 | Frame Shift Del (DEL) | VAF 104/227 reads (46%) | catalogued as rs756606329, COSV53699502; called by mutect2, varscan2
- KMT2B | c.5162C>T p.T1721M | Missense Mutation (SNP) | VAF 135/828 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs1308156549, COSV55859059; called by muse, varscan2
- KMT2B | c.6895del p.R2299Gfs*26 | Frame Shift Del (DEL) | VAF 355/811 reads (44%) | catalogued as rs1568382485; called by mutect2, pindel, varscan2
- KMT2C | c.3275G>A p.R1092Q | Missense Mutation (SNP) | VAF 296/595 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs150747860; ClinVar: not provided; called by muse, varscan2
- KNDC1 | c.2183C>T p.T728M | Missense Mutation (SNP) | VAF 320/885 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs566345817, COSV58831384; called by muse, mutect2, varscan2
- KPNA2 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 228/537 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs369989302; called by muse, varscan2
- KRI1 | c.666G>A p.T222= | Splice Region (SNP) | VAF 241/478 reads (50%) | catalogued as rs776247947, COSV100469631; called by muse, varscan2
- KRT74 | c.1277A>G p.Q426R | Missense Mutation (SNP) | VAF 33/566 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144213270; called by muse, mutect2
- KRTAP2-1 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 276/1640 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); catalogued as rs1435605987; called by muse, mutect2, varscan2
- KSR1 | c.437C>T p.T146M (on ENST00000644974 / NM_001367810.1; = p.T9M on NM_014238.2) | Missense Mutation (SNP) | VAF 501/1052 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.137); catalogued as rs761371576; called by muse, mutect2, varscan2
- L3MBTL4 | c.1562G>T p.G521V | Missense Mutation (SNP) | VAF 335/702 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV53123806; called by muse, mutect2, varscan2
- LAPTM4B | c.750_752del p.L251del (on ENST00000445593; = p.L160del on NM_018407.6) | In Frame Del (DEL) | VAF 72/330 reads (22%) | catalogued as rs777944332; called by pindel, varscan2
- LAPTM5 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 116/580 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs762845113, COSV99612501; called by muse, varscan2
- LMTK3 | c.4131dup p.E1378Rfs*162 | Frame Shift Ins (INS) | VAF 225/550 reads (41%) | catalogued as rs758225154; called by mutect2, varscan2
- LPAR5 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 228/1256 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs764003076, COSV61693055; called by muse, mutect2, varscan2
- LPCAT2 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 222/475 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV50896497; called by muse, mutect2, varscan2
- LPCAT3 | c.1348-2A>G p.X450_splice | Splice Site (SNP) | VAF 77/439 reads (18%) | catalogued as rs1443920755; called by muse, mutect2, varscan2
- LRP1 | c.4267C>T p.R1423C | Missense Mutation (SNP) | VAF 458/1003 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54520303; called by muse, mutect2, varscan2
- LRRC66 | c.1037G>T p.R346M | Missense Mutation (SNP) | VAF 138/600 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV58634512; called by muse, mutect2, varscan2
- LRRIQ1 | c.830dup p.N277Kfs*9 | Frame Shift Ins (INS) | VAF 30/202 reads (15%) | catalogued as rs1449420475; called by mutect2, varscan2
- LRRTM3 | c.1199G>A p.G400E | Missense Mutation (SNP) | VAF 254/714 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.088); catalogued as COSV63669719; called by muse, mutect2, varscan2
- LUZP2 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 304/495 reads (61%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV61208270; called by muse, varscan2
- MAN2A1 | c.1916del p.N639Ifs*2 | Frame Shift Del (DEL) | VAF 187/231 reads (81%) | catalogued as rs758700583; called by mutect2, pindel, varscan2
- MAP3K15 | c.3851G>A p.R1284Q | Missense Mutation (SNP) | VAF 145/299 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV100135161; called by muse, mutect2, varscan2
- MAPK14 | c.641C>A p.A214D | Missense Mutation (SNP) | VAF 221/474 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57696494; called by muse, mutect2, varscan2
- MAPT | c.1202C>T p.A401V (on ENST00000262410 / NM_001377265.1; = p.A326V on NM_016835.4) | Missense Mutation (SNP) | VAF 591/1340 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); catalogued as COSV52239842; called by muse, mutect2, varscan2
- MARK2 | c.1582C>T p.R528C (on ENST00000402010 / NM_001039469.2; = p.R494C on NM_017490.4) | Missense Mutation (SNP) | VAF 502/503 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs972173237, COSV59282370; called by muse, mutect2, varscan2
- MAST1 | c.3196C>A p.R1066S | Missense Mutation (SNP) | VAF 372/770 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV52243316; called by muse, varscan2
- MAST4 | c.6599C>T p.P2200L (on ENST00000403625 / NM_001164664.2; = p.P2011L on NM_015183.3) | Missense Mutation (SNP) | VAF 519/857 reads (61%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.005); catalogued as rs986498579, COSV104375397; called by muse, mutect2, varscan2
- MBNL1 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 362/564 reads (64%) | SIFT tolerated (0.23); PolyPhen benign (0.203); catalogued as rs780538995, COSV56828467, COSV56836247; called by muse, varscan2
- MBTD1 | c.662G>T p.W221L | Missense Mutation (SNP) | VAF 296/654 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64504345; called by muse, mutect2, varscan2
- MCF2L | c.2198G>A p.R733H (on ENST00000375608; = p.R701H on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 395/650 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs774936427, COSV56175265; called by muse, mutect2, varscan2
- MCFD2 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 257/377 reads (68%) | SIFT tolerated (0.18); PolyPhen benign (0.204); catalogued as rs1162286700, COSV60177920; called by muse, mutect2, varscan2
- MCTP2 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 148/626 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.314); catalogued as rs571941802, COSV59144810; called by muse, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 88/242 reads (36%) | catalogued as rs1180255648; called by pindel, varscan2
- MED13L | c.5585A>G p.N1862S | Missense Mutation (SNP) | VAF 161/305 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs1397464926; called by muse, mutect2, varscan2
- MEF2B | c.542-2A>G p.X181_splice | Splice Site (SNP) | VAF 442/860 reads (51%) | catalogued as COSV50766234; called by muse, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 398/909 reads (44%) | catalogued as rs762115034; called by mutect2, varscan2
- MICAL2 | c.2498C>T p.A833V | Missense Mutation (SNP) | VAF 222/788 reads (28%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.044); catalogued as rs763464953, COSV56319816; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 292/651 reads (45%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MMP25 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 459/985 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs143925847, COSV60678875; called by muse, mutect2, varscan2
- MMP9 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 140/711 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745558432, COSV63434254; called by muse, mutect2, varscan2
- MORN1 | c.747C>T p.S249= | Splice Region (SNP) | VAF 248/468 reads (53%) | catalogued as rs751372454, COSV101047542; called by muse, varscan2
- MPO | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 310/611 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs761949874, COSV56561209; called by muse, mutect2, varscan2
- MRC2 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 435/949 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs546895407, COSV57636441; called by muse, mutect2, varscan2
- MRE11 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 175/426 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs767097795; ClinVar: uncertain significance; called by muse, varscan2
- MRM2 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 282/738 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54247956; called by muse, mutect2, varscan2
- MROH5 | c.92del p.P31Lfs*6 | Frame Shift Del (DEL) | VAF 64/465 reads (14%) | catalogued as rs748849454; called by pindel, varscan2
- MRPS11 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 183/529 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); catalogued as rs762797699; called by muse, mutect2, varscan2
- MTA1 | c.1867C>T p.L623F | Missense Mutation (SNP) | VAF 130/759 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs925179341; called by mutect2, varscan2
- MUC1 | c.401dup p.A135Sfs*873 (on ENST00000611571 / NM_001371720.1; = p.A135Sfs*86 on NM_001204285.2) | Frame Shift Ins (INS) | VAF 160/528 reads (30%) | catalogued as rs1557836992; ClinVar: uncertain significance; called by mutect2, varscan2
- MUC16 | c.34094C>T p.T11365I | Missense Mutation (SNP) | VAF 290/598 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.014); catalogued as rs777642205; called by muse, mutect2, varscan2
- MUC17 | c.1025G>A p.S342N | Missense Mutation (SNP) | VAF 456/901 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs1164758470; called by muse, mutect2, varscan2
- MUC17 | c.5107G>C p.A1703P | Missense Mutation (SNP) | VAF 372/816 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV60301305; called by muse, mutect2, varscan2
- MVK | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 362/748 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs372166675; called by muse, varscan2
- MYCBPAP | c.1196C>A p.P399H | Missense Mutation (SNP) | VAF 80/537 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100088258; called by muse, varscan2
- MYO1B | c.2108G>A p.R703H | Missense Mutation (SNP) | VAF 87/404 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as rs765685451; called by muse, mutect2, varscan2
- MYOG | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 391/797 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.277); catalogued as rs200354483, COSV54095180; called by muse, mutect2, varscan2
- MYOM3 | c.4207G>T p.G1403C | Missense Mutation (SNP) | VAF 186/706 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773501383, COSV58391370, COSV58399053; called by muse, mutect2, varscan2
- NALCN | c.1596A>C p.E532D | Missense Mutation (SNP) | VAF 94/357 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.406); catalogued as rs778469231; called by muse, mutect2, varscan2
- NCAPG2 | c.2900G>A p.R967Q | Missense Mutation (SNP) | VAF 259/535 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs527840789; called by muse, mutect2, varscan2
- NDC80 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 58/428 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as rs766519914, COSV55247894; called by muse, varscan2
- NDUFA7 | c.137G>A p.S46N | Missense Mutation (SNP) | VAF 322/654 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.46); catalogued as COSV56847732; called by muse, varscan2
- NET1 | c.941G>A p.R314H (on ENST00000355029 / NM_001047160.3; = p.R260H on NM_005863.5) | Missense Mutation (SNP) | VAF 210/610 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1205204380; called by muse, varscan2
- NEXMIF | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 361/805 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50025295; called by muse, mutect2, varscan2
- NIBAN2 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 234/235 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs762563150, COSV64825334; called by muse, mutect2, varscan2
- NIPBL | c.7801A>G p.M2601V | Missense Mutation (SNP) | VAF 251/550 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as rs759275114; called by muse, mutect2, varscan2
- NKTR | c.1847del p.P616Lfs*21 | Frame Shift Del (DEL) | VAF 275/293 reads (94%) | catalogued as rs763440516; called by mutect2, varscan2
- NKX1-1 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 353/725 reads (49%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as rs1469500275; called by muse, mutect2, varscan2
- NOC4L | c.907del p.X303_splice | Splice Site (DEL) | VAF 237/577 reads (41%) | catalogued as rs765400964; called by mutect2, pindel, varscan2
- NOLC1 | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 257/454 reads (57%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs141424326; called by muse, varscan2
- NOTCH4 | c.4423C>T p.R1475C | Missense Mutation (SNP) | VAF 258/1465 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV100900296; called by muse, mutect2, varscan2
- NPAP1 | c.3334G>A p.G1112R | Missense Mutation (SNP) | VAF 121/519 reads (23%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.156); catalogued as COSV100276006; called by muse, mutect2, varscan2
- NPNT | c.308G>A p.R103K | Missense Mutation (SNP) | VAF 97/431 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59755157; called by muse, mutect2, varscan2
- NPTXR | c.322del p.Q108Sfs*108 | Frame Shift Del (DEL) | VAF 165/1179 reads (14%) | catalogued as rs1156759427; called by mutect2, pindel, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 112/405 reads (28%) | catalogued as rs774343392; called by mutect2, varscan2
- NR4A3 | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 562/583 reads (96%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV58243212; called by muse, mutect2, varscan2
- NSL1 | c.796del p.Q266Rfs*41 | Frame Shift Del (DEL) | VAF 83/469 reads (18%) | catalogued as rs1270934107; called by mutect2, pindel, varscan2
- NT5DC3 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 222/547 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as rs758485823; called by muse, mutect2, varscan2
- NTRK3 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 326/872 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs201426743, COSV58111825; called by muse, mutect2, varscan2
- NTSR1 | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 350/903 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs368494260; called by muse, mutect2, varscan2
- NUMA1 | c.5356dup p.L1786Pfs*18 | Frame Shift Ins (INS) | VAF 96/306 reads (31%) | catalogued as rs1184519643; called by mutect2, pindel, varscan2
- NUMBL | c.902T>C p.V301A | Missense Mutation (SNP) | VAF 474/974 reads (49%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.755); catalogued as rs1192526014; called by muse, mutect2, varscan2
- OBSCN | c.10664C>A p.A3555D | Missense Mutation (SNP) | VAF 93/550 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52843823; called by muse, mutect2, varscan2
- OBSL1 | c.4583G>A p.R1528H | Missense Mutation (SNP) | VAF 472/727 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs759240898, COSV54705958; called by muse, mutect2, varscan2
- OLA1 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 64/266 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs375033952, COSV52969227; called by muse, mutect2, varscan2
- OPLAH | c.3221C>T p.A1074V | Missense Mutation (SNP) | VAF 570/1540 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1554757941, COSV70677818; called by muse, mutect2, varscan2
- OR10G8 | c.20T>G p.L7R | Missense Mutation (SNP) | VAF 300/601 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV70908170; called by muse, mutect2, varscan2
- OR10H3 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 415/854 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs778942345, COSV59943941; called by muse, mutect2, varscan2
- OR10T2 | c.518A>T p.N173I | Missense Mutation (SNP) | VAF 227/470 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57780033; called by muse, mutect2, varscan2
- OR1C1 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 212/389 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs372819870, COSV101376227; called by muse, mutect2, varscan2
- OR2A4 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 169/910 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV59575638; called by muse, mutect2, varscan2
- OR2W3 | c.850del p.L284Sfs*14 | Frame Shift Del (DEL) | VAF 110/321 reads (34%) | catalogued as rs1268396241; called by mutect2, pindel
- OR4D6 | c.40T>C p.F14L | Missense Mutation (SNP) | VAF 21/313 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0.05); catalogued as COSV100271530; called by muse, mutect2
- OR4N2 | c.512C>A p.P171Q | Missense Mutation (SNP) | VAF 152/2027 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs750788192, COSV60053250; called by muse, mutect2
- OR51E1 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 285/461 reads (62%) | SIFT tolerated (1); PolyPhen possibly damaging (0.699); catalogued as rs370898634, COSV67809759; called by muse, mutect2, varscan2
- OR51E1 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 147/521 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200993659, COSV67810326; called by muse, mutect2, varscan2
- OR5H2 | c.270C>A p.F90L | Missense Mutation (SNP) | VAF 262/586 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV100788702, COSV62350300; called by muse, mutect2, varscan2
- OR5H8 | c.307dup p.S103Ffs*19 | Frame Shift Ins (INS) | VAF 66/460 reads (14%) | catalogued as rs755434418; called by mutect2, varscan2
- P4HA2 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 413/414 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs147398523, COSV51324938; called by muse, mutect2, varscan2
- PCBD2 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 48/314 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.309); catalogued as rs546855178; called by muse, mutect2, varscan2
- PCDH10 | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 219/660 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52099108, COSV99993103; called by muse, varscan2
- PCDHA3 | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 237/1024 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV63540052; called by muse, mutect2, varscan2
- PCDHB10 | c.2189C>T p.P730L | Missense Mutation (SNP) | VAF 38/765 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.033); catalogued as rs1340169572; called by muse, mutect2
- PCDHGA2 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 143/648 reads (22%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.001); catalogued as rs746073058, COSV54013789; called by muse, mutect2, varscan2
- PCDHGA6 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 50/1043 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs1415388106, COSV53989482; called by muse, mutect2
- PCDHGA9 | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 514/516 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs199517824; called by muse, mutect2, varscan2
- PCNT | c.2581G>A p.A861T | Missense Mutation (SNP) | VAF 123/810 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); catalogued as rs377283848, COSV64027964; called by muse, mutect2, varscan2
- PDE6B | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 276/606 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs182545478; called by muse, mutect2, varscan2
- PDLIM3 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 159/802 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1194638169; called by muse, mutect2, varscan2
- PDS5B | c.3954del p.K1318Nfs*76 | Frame Shift Del (DEL) | VAF 182/310 reads (59%) | catalogued as rs747131399; called by mutect2, varscan2
- PER1 | c.1810G>A p.V604I | Missense Mutation (SNP) | VAF 695/699 reads (99%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs753045671; called by muse, mutect2, varscan2
- PGAM5 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 320/676 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as rs144537165; called by muse, varscan2
- PGLS | c.185T>C p.V62A | Missense Mutation (SNP) | VAF 633/1376 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1381699018; called by muse, mutect2
- PIEZO1 | c.7169G>A p.R2390Q | Missense Mutation (SNP) | VAF 186/1020 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.022); catalogued as rs377011269, COSV56343541; called by muse, mutect2, varscan2
- PIGO | c.1361del p.G454Vfs*31 | Frame Shift Del (DEL) | VAF 288/422 reads (68%) | catalogued as COSV53054111, COSV53054694; called by pindel, varscan2
- PIP5K1C | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 494/1010 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs377291771, COSV58950241; called by muse, mutect2, varscan2
- PKMYT1 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 160/944 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs1411441085, COSV99233939; called by muse, mutect2, varscan2
- PLD5 | c.1121G>A p.R374Q (on ENST00000442594; = p.R312Q on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 253/547 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV59163972; called by muse, mutect2, varscan2
- PLEC | c.7072C>T p.R2358C (on ENST00000322810 / NM_201380.4; = p.R2248C on NM_000445.5) | Missense Mutation (SNP) | VAF 216/1562 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs377275586; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHM3 | c.1513C>T p.R505* | Nonsense Mutation (SNP) | VAF 207/380 reads (54%) | catalogued as rs1416993669, COSV66815589; called by muse, mutect2, varscan2
- PLOD2 | c.1975C>G p.R659G | Missense Mutation (SNP) | VAF 42/264 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.617); catalogued as COSV51469342; called by muse, mutect2, varscan2
- PNMA5 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 162/958 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs1054102157, COSV62626122; called by muse, mutect2, varscan2
- PNMT | c.627dup p.H210Afs*27 | Frame Shift Ins (INS) | VAF 104/744 reads (14%) | catalogued as rs771451039; called by mutect2, pindel, varscan2
- POLE | c.4477G>A p.A1493T | Missense Mutation (SNP) | VAF 347/686 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs748522633; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.2335A>G p.T779A | Missense Mutation (SNP) | VAF 29/1097 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.059); catalogued as rs1315441740; called by muse, mutect2
- PPEF2 | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 126/247 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99714719; called by muse, mutect2, varscan2
- PPFIA1 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 102/656 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs750251702, COSV54134332; called by muse, mutect2, varscan2
- PPP2R3B | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 384/788 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.383); catalogued as rs760244257, COSV66813342; called by muse, varscan2
- PPP3CA | c.230del p.N77Ifs*22 | Frame Shift Del (DEL) | VAF 90/305 reads (30%) | catalogued as rs1250808026; called by mutect2, varscan2
- PPP5C | c.46dup p.R16Pfs*7 | Frame Shift Ins (INS) | VAF 278/618 reads (45%) | catalogued as rs766639242; called by mutect2, varscan2
- PRB4 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 121/777 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.036); catalogued as COSV54398610; called by muse, mutect2, varscan2
- PRDM16 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 251/565 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1407647352, COSV54605049, COSV54606419; called by muse, mutect2, varscan2
- PRDM9 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 181/440 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs112157044; called by muse, varscan2
- PRG4 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 202/458 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.453); catalogued as rs369769286, COSV66624843; called by muse, mutect2, varscan2
- PRKDC | c.6224C>T p.T2075M | Missense Mutation (SNP) | VAF 137/524 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs769896993, COSV58050642; called by muse, mutect2, varscan2
- PRKDC | c.2845C>T p.P949S | Missense Mutation (SNP) | VAF 235/597 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.226); catalogued as rs772980444; called by muse, mutect2, varscan2
- PRKX | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 328/676 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1348033937; called by muse, mutect2, varscan2
- PROB1 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 173/1238 reads (14%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.003); catalogued as rs1199756962; called by muse, mutect2, varscan2
- PROS1 | c.1553C>T p.T518M | Missense Mutation (SNP) | VAF 273/548 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as rs373336653; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PROX1 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 306/640 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1374775160, COSV99800417; called by muse, mutect2, varscan2
- PRPF3 | c.1922G>A p.R641Q | Missense Mutation (SNP) | VAF 219/470 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as rs201590000; ClinVar: uncertain significance; called by muse, varscan2
- PRR5 | c.494C>T p.A165V (on ENST00000336985 / NM_181333.4; = p.A156V on NM_015366.4) | Missense Mutation (SNP) | VAF 942/1590 reads (59%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as rs572406576; called by muse, varscan2
- PRSS38 | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 454/874 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as rs373887552; called by muse, mutect2, varscan2
- PSMG4 | c.161T>C p.M54T | Missense Mutation (SNP) | VAF 22/728 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs899898819; called by muse, mutect2
- PUM2 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 117/332 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.695); catalogued as COSV100163837, COSV57580987; called by muse, varscan2
- PVRIG | c.236del p.G79Afs*245 | Frame Shift Del (DEL) | VAF 290/740 reads (39%) | catalogued as rs768997455; called by mutect2, pindel, varscan2
- PWWP2B | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 366/1012 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs965289685; called by muse, mutect2, varscan2
- PXMP4 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 108/637 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as rs571523348; called by muse, mutect2, varscan2
- PYHIN1 | c.1048del p.T350Qfs*6 | Frame Shift Del (DEL) | VAF 129/301 reads (43%) | catalogued as COSV63722536; called by mutect2, pindel, varscan2
- RAB11FIP1 | c.37del p.A13Pfs*10 | Frame Shift Del (DEL) | VAF 226/643 reads (35%) | catalogued as rs35243840; called by mutect2, varscan2
- RANBP2 | c.3595G>A p.A1199T | Missense Mutation (SNP) | VAF 122/417 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs978251652; called by muse, mutect2, varscan2
- RASAL1 | c.2014G>A p.A672T | Missense Mutation (SNP) | VAF 149/915 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.041); catalogued as rs745903688; called by muse, mutect2, varscan2
- RASAL3 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 97/576 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1043531115; called by muse, mutect2, varscan2
- RASEF | c.748A>G p.I250V | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.2); catalogued as rs201661045; called by muse, mutect2
- RASGRP4 | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 340/661 reads (51%) | catalogued as rs766578361, COSV99498370; called by muse, mutect2, varscan2
- RBBP8NL | c.519C>A p.H173Q | Missense Mutation (SNP) | VAF 127/709 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs145553586; called by muse, mutect2, varscan2
- RBFA | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 221/222 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as rs139845183; called by muse, mutect2, varscan2
- RBM10 | c.2111C>T p.A704V | Missense Mutation (SNP) | VAF 392/830 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs868977796; called by muse, mutect2, varscan2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 229/238 reads (96%) | catalogued as COSV56484832; called by mutect2, varscan2
- RBMXL1 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 425/836 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs374309282; called by muse, mutect2, varscan2
- RBMXL3 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 667/1300 reads (51%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs1385235583; called by muse, varscan2
- REPIN1 | c.1116dup p.S373Lfs*228 | Frame Shift Ins (INS) | VAF 372/1008 reads (37%) | catalogued as rs759247453; called by mutect2, varscan2
- REPIN1 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 651/1375 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1213016608; called by muse, mutect2, varscan2
- RILPL1 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 364/691 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1246793683; called by muse, mutect2, varscan2
- RNF213 | c.12949C>T p.R4317W | Missense Mutation (SNP) | VAF 206/410 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs759256018, COSV60407022; called by muse, varscan2
- ROS1 | c.532C>T p.L178F | Missense Mutation (SNP) | VAF 280/597 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs771282907; called by muse, mutect2, varscan2
- RP1 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 172/468 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs369804244, COSV55114432; called by muse, mutect2, varscan2
- RP1 | c.2572del p.I858Yfs*37 | Frame Shift Del (DEL) | VAF 133/395 reads (34%) | catalogued as rs1214953601; called by mutect2, pindel, varscan2
- RP1L1 | c.2450C>T p.A817V | Missense Mutation (SNP) | VAF 272/273 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs1187441272, COSV66754347; called by muse, mutect2, varscan2
- RPP30 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 288/631 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.818); catalogued as rs137907824; called by muse, varscan2
- RPRD2 | c.4048G>T p.G1350W | Missense Mutation (SNP) | VAF 432/977 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV64818724; called by muse, mutect2, varscan2
- RRM1 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 317/514 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56162867; called by muse, mutect2, varscan2
- RRP1 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 149/773 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs530647149; called by muse, mutect2, varscan2
- RRP1 | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 620/1278 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs749236769; called by muse, mutect2, varscan2
- RRP7A | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 66/726 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.562); catalogued as rs1465956121; called by muse, mutect2
- RSPH10B | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 139/281 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.078); catalogued as rs749914563; called by muse, mutect2, varscan2
- RXFP1 | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 232/408 reads (57%) | catalogued as rs200071060, COSV57055994; called by muse, mutect2, varscan2
- RYR1 | c.2079del p.Y694Tfs*36 | Frame Shift Del (DEL) | VAF 304/699 reads (43%) | catalogued as rs1568451501; called by mutect2, pindel, varscan2
- SALL4 | c.2983del p.V995Ffs*14 | Frame Shift Del (DEL) | VAF 316/559 reads (57%) | catalogued as rs753320334; called by mutect2, varscan2
- SCAF1 | c.3540dup p.T1181Hfs*10 | Frame Shift Ins (INS) | VAF 283/700 reads (40%) | catalogued as rs769836700; called by mutect2, varscan2
- SCAF4 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 179/405 reads (44%) | catalogued as rs1439594249, COSV54584476, COSV54585696; called by muse, mutect2, varscan2
- SCARF1 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 818/826 reads (99%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs867533840, COSV53958347, COSV53961566; called by muse, mutect2, varscan2
- SDK1 | c.5350G>A p.A1784T | Missense Mutation (SNP) | VAF 216/620 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761076885, COSV67355271; called by muse, mutect2, varscan2
- SEL1L | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 104/711 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.171); catalogued as COSV60919463; called by muse, varscan2
- SERTAD2 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 428/693 reads (62%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs772856400, COSV57641417; called by muse, varscan2
- SGO2 | c.1929del p.G644Vfs*18 | Frame Shift Del (DEL) | VAF 82/265 reads (31%) | catalogued as rs1260834379; called by mutect2, varscan2
- SH3BP1 | c.1735del p.Q579Rfs*79 | Frame Shift Del (DEL) | VAF 187/610 reads (31%) | catalogued as rs70950549; called by pindel, varscan2
- SH3BP5L | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 206/1095 reads (19%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.007); catalogued as rs759575065; called by muse, mutect2, varscan2
- SH3RF3 | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 124/416 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1451660266; called by muse, varscan2
- SHANK1 | c.4354G>A p.A1452T | Missense Mutation (SNP) | VAF 728/1504 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs1469441882; called by muse, varscan2
- SHANK3 | c.4504C>T p.R1502C | Missense Mutation (SNP) | VAF 441/1149 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs575384100; called by muse, mutect2, varscan2
- SHISAL1 | c.506del p.P169Qfs*23 | Frame Shift Del (DEL) | VAF 102/907 reads (11%) | catalogued as rs1569218027; called by mutect2, pindel, varscan2
- SHPRH | c.495del p.E166Nfs*3 | Frame Shift Del (DEL) | VAF 268/526 reads (51%) | catalogued as rs1469942319; called by mutect2, varscan2
- SHROOM3 | c.3193G>A p.G1065S | Missense Mutation (SNP) | VAF 300/874 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.453); catalogued as rs775439655; called by muse, mutect2, varscan2
- SIAH3 | c.706G>A p.V236I | Missense Mutation (SNP) | VAF 320/591 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as rs750047881, COSV68552598; called by muse, mutect2, varscan2
- SKOR2 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 492/499 reads (99%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.691); catalogued as COSV68550018; called by muse, mutect2, varscan2
- SLC15A1 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 252/441 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs764483622, COSV64732066; called by muse, mutect2, varscan2
- SLC25A10 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 163/866 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773565252; called by muse, mutect2, varscan2
- SLC27A3 | c.1636C>T p.P546S (on ENST00000271857; = p.P418S on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 611/1300 reads (47%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as rs1303528906; called by muse, mutect2, varscan2
- SLC2A7 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 205/338 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs773308377, COSV68901454; called by muse, mutect2, varscan2
- SLC49A3 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 145/328 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as rs747020127, COSV59141639; called by muse, mutect2, varscan2
- SLC5A10 | c.1213G>A p.G405S (on ENST00000395645 / NM_001042450.4; = p.G421S on NM_152351.5) | Missense Mutation (SNP) | VAF 295/297 reads (99%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs780119794; called by muse, mutect2, varscan2
- SLC5A11 | c.1999G>A p.A667T | Missense Mutation (SNP) | VAF 292/658 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs368113331; called by muse, varscan2
- SLC9C1 | c.3005G>A p.G1002E | Missense Mutation (SNP) | VAF 217/403 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1454329029; called by muse, varscan2
- SLITRK6 | c.2308G>A p.G770R | Missense Mutation (SNP) | VAF 222/368 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs762216866, COSV101233227; called by muse, mutect2, varscan2
- SMG1 | c.3059G>A p.R1020H | Missense Mutation (SNP) | VAF 26/267 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1248193781, COSV67173781; called by muse, mutect2, varscan2
- SNTA1 | c.583del p.L195Ffs*23 | Frame Shift Del (DEL) | VAF 297/689 reads (43%) | catalogued as rs1443071118; called by mutect2, pindel, varscan2
- SNTB2 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 286/603 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs758452589; called by muse, mutect2, varscan2
- SOGA3 | c.2470C>T p.R824C | Missense Mutation (SNP) | VAF 547/549 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs775544839, COSV64106238; called by muse, mutect2, varscan2
- SORBS2 | c.2506C>T p.R836C (on ENST00000284776 / NM_021069.5; = p.R402C on NM_003603.6) | Missense Mutation (SNP) | VAF 176/286 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.28); catalogued as rs756993379; called by muse, mutect2, varscan2
- SORCS1 | c.558+2del p.X186_splice | Splice Site (DEL) | VAF 174/330 reads (53%) | catalogued as COSV53901348; called by mutect2, pindel, varscan2
- SOS2 | c.2677G>A p.E893K | Missense Mutation (SNP) | VAF 149/327 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.03); catalogued as COSV53566519; called by muse, mutect2, varscan2
- SOX1 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 107/278 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.107); catalogued as rs1465709458; called by muse, mutect2, varscan2
- SOX10 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 603/1611 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.556); catalogued as COSV100329862; called by muse, mutect2, varscan2
- SP5 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 359/978 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs767878015; called by muse, mutect2, varscan2
- SPARCL1 | c.1915G>T p.D639Y | Missense Mutation (SNP) | VAF 172/530 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56805981; called by muse, mutect2, varscan2
- SPDEF | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 387/796 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775855317; called by muse, mutect2, varscan2
- SPHK2 | c.1598C>T p.T533M | Missense Mutation (SNP) | VAF 616/1209 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs760049391; called by muse, mutect2, varscan2
- SPHKAP | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 315/526 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV60869857; called by muse, varscan2
- SRC | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 302/565 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV62440190; called by muse, varscan2
- SREK1IP1 | c.407del p.K136Rfs*22 | Frame Shift Del (DEL) | VAF 76/235 reads (32%) | catalogued as rs772485731; called by mutect2, pindel, varscan2
- SRGAP1 | c.1565T>C p.I522T | Missense Mutation (SNP) | VAF 339/764 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs202173847; called by muse, mutect2, varscan2
- SRP68 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 164/394 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1222515803; called by muse, varscan2
- ST3GAL6 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 188/484 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.088); catalogued as COSV54585976; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.478C>T p.L160F | Missense Mutation (SNP) | VAF 34/984 reads (3%) | PolyPhen probably damaging (0.998); catalogued as rs1490229305; called by muse, mutect2
- STIM2 | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 123/256 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as rs201149830, COSV99402981; called by muse, mutect2, varscan2
- STRIP1 | c.1705C>A p.R569S | Missense Mutation (SNP) | VAF 220/443 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100874020; called by muse, mutect2, varscan2
- STUM | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 195/1038 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.842); catalogued as rs1245326170; called by mutect2, varscan2
- SUGCT | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 160/484 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781200920, COSV59343951; called by muse, mutect2, varscan2
- SUPT6H | c.2569G>A p.A857T | Missense Mutation (SNP) | VAF 248/522 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.797); catalogued as rs775521641; called by muse, mutect2, varscan2
- SYCP2L | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 198/365 reads (54%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as rs370377149; called by muse, mutect2, varscan2
- SYNGAP1 | c.3929C>T p.T1310M | Missense Mutation (SNP) | VAF 272/584 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs796430835, COSV99538062; called by muse, mutect2, varscan2
- TAMM41 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 48/612 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.039); catalogued as rs374882230; called by muse, mutect2
- TAOK2 | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 472/948 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs779224250; called by muse, mutect2, varscan2
- TAS1R1 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 831/1323 reads (63%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.677); catalogued as rs530483330; called by muse, mutect2, varscan2
- TAS2R9 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 405/789 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as rs756576629, COSV53688628; called by muse, mutect2, varscan2
- TBC1D17 | c.1435G>C p.D479H | Missense Mutation (SNP) | VAF 213/480 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV55581042; called by muse, mutect2, varscan2
- TBXAS1 | c.1199C>T p.T400M | Missense Mutation (SNP) | VAF 370/774 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs78666490, COSV54946635; called by muse, varscan2
- TCHH | c.3069dup p.D1024Rfs*194 | Frame Shift Ins (INS) | VAF 281/778 reads (36%) | catalogued as rs1298090051; called by pindel, varscan2
- TCHHL1 | c.1079C>A p.S360Y | Missense Mutation (SNP) | VAF 250/537 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV64285813; called by muse, mutect2, varscan2
- TDRD12 | c.3378del p.Q1127Rfs*47 (on ENST00000444215; = p.Q1132Rfs*57 on NM_001366102.1) | Frame Shift Del (DEL) | VAF 186/486 reads (38%) | catalogued as rs1331884293; called by mutect2, pindel, varscan2
- TDRD5 | c.2783C>T p.S928F | Missense Mutation (SNP) | VAF 211/501 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV99675208; called by muse, mutect2, varscan2
- TEX43 | c.241_242del p.L81Vfs*6 | Frame Shift Del (DEL) | VAF 70/300 reads (23%) | catalogued as rs779521055; called by pindel, varscan2
- TFDP3 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 452/958 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.556); catalogued as rs777030815, COSV59536621; called by muse, mutect2
- TFPI2 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 385/814 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.663); catalogued as rs778950207; called by muse, mutect2, varscan2
- THBS3 | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 282/553 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772718514, COSV64248425; called by muse, mutect2, varscan2
- THOP1 | c.1771+2T>C p.X591_splice | Splice Site (SNP) | VAF 93/520 reads (18%) | catalogued as rs749180196; called by muse, varscan2
- THSD7B | c.2183G>A p.R728H | Missense Mutation (SNP) | VAF 162/283 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs370266523; called by muse, mutect2, varscan2
- TIAM1 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 343/730 reads (47%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs758452455, COSV54542399; called by muse, mutect2, varscan2
- TIPARP | c.1423C>T p.R475W | Missense Mutation (SNP) | VAF 116/493 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as rs150068199; called by muse, mutect2, varscan2
- TLE2 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 335/748 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as rs776121050; called by muse, mutect2, varscan2
- TLK2 | c.691_693del p.K231del | In Frame Del (DEL) | VAF 62/182 reads (34%) | catalogued as rs779826427; called by pindel, varscan2
- TLL1 | c.2173G>A p.A725T | Missense Mutation (SNP) | VAF 89/307 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99286821; called by muse, mutect2, varscan2
- TLL2 | c.970G>A p.V324I | Missense Mutation (SNP) | VAF 92/530 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs61743696, COSV63570758; called by muse, mutect2, varscan2
- TLX1 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 32/786 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100930059, COSV64622648; called by muse, mutect2
- TMCC2 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 453/1100 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.749); catalogued as rs1182470181; called by muse, varscan2
- TMEM130 | c.804-1G>A p.X268_splice | Splice Site (SNP) | VAF 235/498 reads (47%) | catalogued as rs782243837; called by muse, varscan2
- TMEM151A | c.1173dup p.A392Rfs*53 | Frame Shift Ins (INS) | VAF 338/844 reads (40%) | catalogued as rs1158034577; called by pindel, varscan2
- TMEM201 | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 482/832 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs928354065, COSV61160846; called by muse, mutect2, varscan2
- TMEM54 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 239/649 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368310171; called by muse, mutect2, varscan2
- TMPRSS9 | c.2800C>T p.R934C (on ENST00000648592; = p.R900C on NM_182973.2) | Missense Mutation (SNP) | VAF 576/1258 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs760660660, COSV53115519; called by muse, mutect2, varscan2
- TMTC1 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 123/686 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.114); catalogued as rs988961203; called by muse, mutect2, varscan2
- TNFSF12 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 848/850 reads (100%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs758038102, COSV53434011; called by muse, varscan2
- TNIP2 | c.657C>T p.H219= | Splice Region (SNP) | VAF 124/306 reads (41%) | catalogued as rs758835523; called by muse, mutect2, varscan2
- TNIP2 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 263/527 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs201862092, COSV59569770; called by muse, mutect2, varscan2
- TNPO2 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 346/742 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs369773308; called by muse, mutect2, varscan2
- TP53I11 | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 290/576 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs762010357; called by muse, varscan2
- TP53TG5 | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 274/438 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs567269564; called by muse, mutect2, varscan2
- TRABD | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 323/938 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1305918751; called by muse, mutect2, varscan2
- TRAC | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 350/712 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750169372; called by muse, varscan2
- TRAF2 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 436/437 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as rs755436517, COSV56040676; called by muse, varscan2
- TRAF3IP3 | c.1576C>T p.R526* | Nonsense Mutation (SNP) | VAF 230/462 reads (50%) | catalogued as rs1470581004, COSV50551177; called by muse, mutect2, varscan2
- TRAM1L1 | c.394del p.S132Lfs*9 | Frame Shift Del (DEL) | VAF 32/214 reads (15%) | catalogued as rs757906221; called by pindel, varscan2
- TRIM32 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 350/351 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs763720824, COSV100525687; called by muse, mutect2, varscan2
- TRIM56 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 499/996 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs199890101, COSV60161217; called by muse, mutect2, varscan2
- TRIM67 | c.265G>T p.G89C | Missense Mutation (SNP) | VAF 190/1215 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.453); catalogued as rs961586187; called by mutect2, varscan2
- TRIO | c.7050del p.V2351Cfs*62 | Frame Shift Del (DEL) | VAF 274/594 reads (46%) | catalogued as rs746654944; called by mutect2, pindel, varscan2
- TRPA1 | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 246/734 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.517); catalogued as rs141174965, COSV100085577; called by muse, mutect2, varscan2
- TRPC6 | c.2552C>T p.P851L | Missense Mutation (SNP) | VAF 137/342 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV100723732; called by muse, mutect2, varscan2
- TRPV1 | c.2071G>A p.A691T | Missense Mutation (SNP) | VAF 374/375 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0.037); catalogued as rs375905892, COSV51518233; called by muse, mutect2, varscan2
- TRPV2 | c.532T>C p.C178R | Missense Mutation (SNP) | VAF 102/554 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1286720079; called by muse, varscan2
- TSNARE1 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 382/1498 reads (26%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as rs148280960, COSV56182027; called by muse, mutect2, varscan2
- TTC34 | c.3119G>A p.R1040H | Missense Mutation (SNP) | VAF 604/1305 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.044); catalogued as rs1027234165; called by muse, mutect2, varscan2
- TTLL13P | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 312/500 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147450804; called by muse, varscan2
- TTN | c.72548G>A p.R24183H (on ENST00000591111; = p.R16759H on NM_003319.4) | Missense Mutation (SNP) | VAF 313/540 reads (58%) | PolyPhen benign (0.007); catalogued as rs376051922; called by muse, mutect2, varscan2
- TTN | c.72323C>T p.A24108V (on ENST00000591111; = p.A16684V on NM_003319.4) | Missense Mutation (SNP) | VAF 335/520 reads (64%) | PolyPhen benign (0.031); catalogued as COSV60190007; called by muse, mutect2, varscan2
- TYRO3 | c.911T>C p.L304S | Missense Mutation (SNP) | VAF 76/753 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); catalogued as COSV99778406; called by muse, mutect2
- TYRO3 | c.1781G>A p.G594D | Missense Mutation (SNP) | VAF 85/631 reads (13%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.975); catalogued as COSV99778028; called by muse, mutect2, varscan2
- UBQLN3 | c.1484C>A p.P495Q | Missense Mutation (SNP) | VAF 121/696 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV61163846; called by muse, mutect2, varscan2
- UBXN6 | c.946G>A p.V316M | Missense Mutation (SNP) | VAF 166/904 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs375533590; called by muse, varscan2
- UNC5C | c.2224C>T p.R742C | Missense Mutation (SNP) | VAF 300/548 reads (55%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV71658775, COSV71660832; called by muse, mutect2
- UNC93B1 | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 133/457 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs765034492; called by muse, varscan2
- UNK | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 412/855 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1454325757; called by muse, mutect2, varscan2
- USH1C | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 203/1055 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs749924388; called by muse, varscan2
- USO1 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 171/287 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752906782; called by muse, mutect2, varscan2
- USP39 | c.1427+1G>A p.X476_splice | Splice Site (SNP) | VAF 54/214 reads (25%) | catalogued as rs768524381, COSV60381344, COSV60381900; called by muse, mutect2, varscan2
- VASP | c.551del p.P184Hfs*84 | Frame Shift Del (DEL) | VAF 88/221 reads (40%) | catalogued as rs762759767; called by mutect2, varscan2
- VIL1 | c.50del p.P17Rfs*73 | Frame Shift Del (DEL) | VAF 83/352 reads (24%) | catalogued as rs1452301630; called by pindel, varscan2
- VIL1 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 211/647 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs761167420; called by muse, mutect2, varscan2
- VN1R2 | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 320/779 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.091); catalogued as rs1394368853; called by muse, mutect2, varscan2
- VNN1 | c.1235G>A p.G412D | Missense Mutation (SNP) | VAF 304/733 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100907702; called by muse, varscan2
- VNN2 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 313/606 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.11); catalogued as rs1204346828; called by muse, varscan2
- VSTM2B | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 170/1094 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs1272340675; called by muse, mutect2, varscan2
- VWDE | c.2100del p.K700Nfs*3 | Frame Shift Del (DEL) | VAF 136/243 reads (56%) | catalogued as rs781003137; called by mutect2, varscan2
- VWF | c.877C>A p.P293T | Missense Mutation (SNP) | VAF 90/598 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99777538; called by muse, varscan2
- WDFY3 | c.3103A>G p.R1035G | Missense Mutation (SNP) | VAF 129/481 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.47); catalogued as rs1344426971; called by muse, mutect2, varscan2
- WDR33 | c.3139C>T p.R1047* | Nonsense Mutation (SNP) | VAF 473/784 reads (60%) | catalogued as rs1297033169, COSV59246969; called by muse, mutect2, varscan2
- WDR45 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 191/1085 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV100540124, COSV59876875; called by muse, mutect2, varscan2
- WDR87 | c.3173A>C p.E1058A | Missense Mutation (SNP) | VAF 279/614 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as rs1333893820; called by muse, mutect2, varscan2
- WIPF1 | c.1079del p.P360Rfs*10 | Frame Shift Del (DEL) | VAF 294/498 reads (59%) | catalogued as rs1559146820; called by mutect2, pindel, varscan2
- WIPI1 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 371/811 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as rs773822577; called by muse, mutect2, varscan2
- WIZ | c.3986G>A p.R1329Q (on ENST00000673675 / NM_001371589.1; = p.R234Q on NM_021241.3) | Missense Mutation (SNP) | VAF 435/912 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs766027386; called by muse, mutect2, varscan2
- WIZ | c.3515G>A p.R1172H | Missense Mutation (SNP) | VAF 477/1009 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568296331; called by muse, mutect2, varscan2
- WIZ | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 327/752 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as rs567582050; called by muse, mutect2, varscan2
- WRNIP1 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 130/362 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs764102921; called by muse, mutect2, varscan2
- ZBTB40 | c.2270G>A p.R757H | Missense Mutation (SNP) | VAF 137/586 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs373118267; called by muse, mutect2, varscan2
- ZBTB8B | c.281A>C p.N94T | Missense Mutation (SNP) | VAF 197/525 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs999335701; called by muse, mutect2, varscan2
- ZC3H7B | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 705/1202 reads (59%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.817); catalogued as rs989258774; called by muse, mutect2, varscan2
- ZDHHC12 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 388/389 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199869993, COSV99403583; called by muse, mutect2, varscan2
- ZFAT | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 395/577 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs755233371, COSV64741530; called by muse, mutect2, varscan2
- ZFAT | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 601/836 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs747833185, COSV64738099; called by muse, mutect2, varscan2
- ZFP3 | c.1417G>A p.G473R | Missense Mutation (SNP) | VAF 120/470 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100603865; called by muse, mutect2, varscan2
- ZFP90 | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 276/561 reads (49%) | catalogued as rs776065123, COSV101238714; called by muse, mutect2, varscan2
- ZFP91 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 178/178 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60158747; called by muse, mutect2, varscan2
- ZFPM2 | c.2674G>A p.G892S | Missense Mutation (SNP) | VAF 213/838 reads (25%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs776822472, COSV65873600; called by muse, mutect2, varscan2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 164/446 reads (37%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF142 | c.3755del p.G1252Dfs*20 (on ENST00000411696 / NM_001379660.1; = p.G1052Dfs*20 on NM_001105537.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 126/526 reads (24%) | catalogued as rs751589999; called by mutect2, varscan2
- ZNF16 | c.1400G>A p.G467E | Missense Mutation (SNP) | VAF 292/968 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs773234511, COSV52764628; called by muse, mutect2, varscan2
- ZNF233 | c.1160T>C p.I387T | Missense Mutation (SNP) | VAF 67/687 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as rs191060748; called by muse, mutect2
- ZNF28 | c.283C>T p.H95Y | Missense Mutation (SNP) | VAF 245/545 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.221); catalogued as COSV60425778; called by muse, mutect2, varscan2
- ZNF311 | c.970del p.T324Pfs*83 | Frame Shift Del (DEL) | VAF 227/696 reads (33%) | catalogued as COSV65853064; called by mutect2, pindel, varscan2
- ZNF324 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 44/590 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as rs200000577; called by muse, mutect2
- ZNF324 | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 665/1410 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1395574827; called by muse, mutect2, varscan2
- ZNF354A | c.937C>A p.L313I | Missense Mutation (SNP) | VAF 313/473 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV59985411; called by muse, mutect2, varscan2
- ZNF385C | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 42/1240 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs782208917; called by muse, mutect2
- ZNF496 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 206/393 reads (52%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.962); catalogued as rs779568946; called by muse, mutect2, varscan2
- ZNF506 | c.345dup p.G116Rfs*3 | Frame Shift Ins (INS) | VAF 152/381 reads (40%) | catalogued as rs1409120867; called by mutect2, varscan2
- ZNF575 | c.359C>A p.P120Q | Missense Mutation (SNP) | VAF 697/1496 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.044); catalogued as rs1198734395, COSV58564643; called by muse, mutect2, varscan2
- ZNF585A | c.1360C>A p.H454N (on ENST00000292841 / NM_001288800.2; = p.H399N on NM_152655.3) | Missense Mutation (SNP) | VAF 266/598 reads (44%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.978); catalogued as COSV99493318, COSV99493700; called by muse, mutect2, varscan2
- ZNF614 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 79/508 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as COSV54548275; called by muse, mutect2, varscan2
- ZNF638 | c.4148C>T p.A1383V | Missense Mutation (SNP) | VAF 85/362 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs749885462; called by muse, mutect2, varscan2
- ZNF644 | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 262/561 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV61348605; called by muse, mutect2, varscan2
- ZNF776 | c.700G>T p.G234* | Nonsense Mutation (SNP) | VAF 372/788 reads (47%) | catalogued as rs778356531, COSV100414236, COSV57815394; called by muse, varscan2
- ZNF777 | c.2237G>A p.R746H | Missense Mutation (SNP) | VAF 568/1184 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV56098169; called by muse, varscan2
- ZNF835 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 498/982 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs774840356, COSV73379453, COSV73379652; called by muse, mutect2, varscan2
- ZNF850 | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 300/600 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs748702950, COSV101648599; called by muse, mutect2, varscan2
- ZNF878 | c.507del p.K169Nfs*44 | Frame Shift Del (DEL) | VAF 208/544 reads (38%) | catalogued as rs773648883, COSV72155908; called by mutect2, pindel, varscan2
- ZSCAN10 | c.1109C>T p.T370I (on ENST00000252463; = p.T425I on NM_032805.3) | Missense Mutation (SNP) | VAF 497/1071 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs1374878211; called by muse, mutect2, varscan2
- ZSWIM1 | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 154/587 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1225498674; called by muse, mutect2, varscan2
- A1BG | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 37/1270 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.435); called by muse, mutect2
- ABCA7 | c.5078A>G p.H1693R | Missense Mutation (SNP) | VAF 80/700 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ABCB10 | c.325G>A p.G109S | Missense Mutation (SNP) | VAF 163/1178 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCB8 | c.125A>G p.Q42R | Missense Mutation (SNP) | VAF 88/494 reads (18%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCC3 | c.1817T>G p.L606R | Missense Mutation (SNP) | VAF 289/590 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCC9 | c.2483A>G p.Q828R | Missense Mutation (SNP) | VAF 258/629 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ABCD3 | c.1470G>A p.W490* | Nonsense Mutation (SNP) | VAF 186/352 reads (53%) | called by muse, varscan2
- ABCG8 | c.1127G>T p.S376I | Missense Mutation (SNP) | VAF 141/408 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ABTB1 | c.1088G>A p.G363D (on ENST00000232744 / NM_172027.3; = p.G221D on NM_032548.3) | Missense Mutation (SNP) | VAF 272/1022 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- AC004593.2 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 267/459 reads (58%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ACTR1A | c.85del p.Q29Rfs*82 | Frame Shift Del (DEL) | VAF 103/266 reads (39%) | called by mutect2, pindel, varscan2
- ADAM32 | c.209del p.L70* | Frame Shift Del (DEL) | VAF 21/36 reads (58%) | called by mutect2, varscan2
- ADAMTS2 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 195/1286 reads (15%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- ADAMTS9 | c.3881C>A p.P1294Q | Missense Mutation (SNP) | VAF 155/419 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- ADCY1 | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 70/332 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- ADCY3 | c.1418G>A p.G473D | Missense Mutation (SNP) | VAF 226/714 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ADGB | c.246del p.F82Lfs*14 | Frame Shift Del (DEL) | VAF 137/289 reads (47%) | called by mutect2, pindel, varscan2
- AFF3 | c.3630G>T p.Q1210H | Missense Mutation (SNP) | VAF 253/427 reads (59%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, varscan2
- AGAP1 | c.1399G>T p.G467C | Missense Mutation (SNP) | VAF 372/582 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- AGAP4 | c.1601del p.K534Sfs*59 | Frame Shift Del (DEL) | VAF 82/240 reads (34%) | called by mutect2, pindel, varscan2
- AK5 | c.907G>T p.D303Y (on ENST00000354567 / NM_174858.3; = p.D277Y on NM_012093.4) | Missense Mutation (SNP) | VAF 85/508 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- AK7 | c.2068C>T p.P690S | Missense Mutation (SNP) | VAF 94/614 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKR7A3 | c.938A>T p.D313V | Missense Mutation (SNP) | VAF 32/836 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.269); called by muse, mutect2
- ALDH1L2 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 24/663 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2
- ALDH7A1 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 371/371 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- ALG10B | c.438dup p.N147* | Frame Shift Ins (INS) | VAF 203/222 reads (91%) | called by mutect2, varscan2
- AMMECR1 | c.220del p.Q74Rfs*89 | Frame Shift Del (DEL) | VAF 386/1010 reads (38%) | called by pindel, varscan2
- ANAPC5 | c.535A>T p.S179C | Missense Mutation (SNP) | VAF 395/799 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- ANK1 | c.2210C>A p.P737H | Missense Mutation (SNP) | VAF 60/302 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKLE2 | c.1784G>A p.G595D | Missense Mutation (SNP) | VAF 174/915 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ANKRD11 | c.7151C>T p.P2384L | Missense Mutation (SNP) | VAF 173/1055 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ANKRD29 | c.881G>T p.S294I | Missense Mutation (SNP) | VAF 83/231 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AOC3 | c.1580del p.K527Rfs*6 | Frame Shift Del (DEL) | VAF 62/371 reads (17%) | called by mutect2, pindel, varscan2
- AP002512.3 | c.605T>C p.V202A | Missense Mutation (SNP) | VAF 91/523 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- APBB2 | c.1322T>C p.V441A (on ENST00000295974 / NM_001166050.2; = p.V442A on NM_004307.2) | Missense Mutation (SNP) | VAF 311/613 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AQP3 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 488/494 reads (99%) | called by muse, varscan2
- AQP6 | c.343del p.A115Lfs*37 | Frame Shift Del (DEL) | VAF 428/455 reads (94%) | called by mutect2, varscan2
- AREL1 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 289/598 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- ARFGEF1 | c.1376T>C p.L459S | Missense Mutation (SNP) | VAF 110/284 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- ARFGEF2 | c.4933G>T p.G1645C | Missense Mutation (SNP) | VAF 86/448 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ARHGEF12 | c.3668G>T p.G1223V | Missense Mutation (SNP) | VAF 256/617 reads (41%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ARID2 | c.4451_4452del p.I1484Sfs*18 | Frame Shift Del (DEL) | VAF 293/364 reads (80%) | called by mutect2, pindel, varscan2
- ARMCX1 | c.1256del p.F419Sfs*16 | Frame Shift Del (DEL) | VAF 201/545 reads (37%) | called by pindel, varscan2
- ARPIN | c.518C>A p.A173D | Missense Mutation (SNP) | VAF 295/472 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASAP2 | c.2357del p.P786Rfs*25 | Frame Shift Del (DEL) | VAF 179/505 reads (35%) | called by mutect2, pindel, varscan2
- ASF1A | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, varscan2
- ASTE1 | c.374A>G p.Q125R | Missense Mutation (SNP) | VAF 166/592 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATAD2 | c.2065G>A p.A689T | Missense Mutation (SNP) | VAF 115/1021 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- ATP10B | c.4235C>T p.S1412L | Missense Mutation (SNP) | VAF 74/630 reads (12%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP13A5 | c.3515C>A p.P1172H | Missense Mutation (SNP) | VAF 270/712 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ATP1A4 | c.371G>A p.S124N | Missense Mutation (SNP) | VAF 87/560 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ATP2A1 | c.1618C>G p.P540A | Missense Mutation (SNP) | VAF 384/827 reads (46%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP2B1 | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 76/500 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP6V0D1 | c.854del p.P285Lfs*15 | Frame Shift Del (DEL) | VAF 220/535 reads (41%) | called by mutect2, pindel, varscan2
- ATRIP | c.1033del p.L345Cfs*31 | Frame Shift Del (DEL) | VAF 14/151 reads (9%) | called by mutect2, pindel
- AUTS2 | c.2339G>T p.G780V | Missense Mutation (SNP) | VAF 366/713 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- AWAT1 | c.515G>A p.G172D | Missense Mutation (SNP) | VAF 434/911 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- B3GNT2 | c.128T>C p.I43T | Missense Mutation (SNP) | VAF 91/412 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- BCOR | c.3462G>T p.E1154D | Missense Mutation (SNP) | VAF 462/1036 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BHLHA15 | c.428del p.E143Gfs*? (on ENST00000314018; = p.E143Gfs*80 on NM_177455.4) | Frame Shift Del (DEL) | VAF 356/849 reads (42%) | called by mutect2, pindel, varscan2
- BMI1 | c.582G>A p.M194I | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- C11orf86 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 291/648 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- C14orf180 | c.251A>G p.D84G | Missense Mutation (SNP) | VAF 209/1019 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- C15orf65 | c.227del p.F76Sfs*27 | Frame Shift Del (DEL) | VAF 106/429 reads (25%) | called by mutect2, pindel, varscan2
- C16orf96 | c.2333T>A p.I778N | Missense Mutation (SNP) | VAF 104/573 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- C1QTNF4 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 339/662 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- C2CD4D | c.1036C>A p.L346M | Missense Mutation (SNP) | VAF 118/922 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- C5orf52 | c.383del p.K128Sfs*3 | Frame Shift Del (DEL) | VAF 148/555 reads (27%) | called by mutect2, varscan2
- C6orf132 | c.944T>G p.I315S | Missense Mutation (SNP) | VAF 36/1103 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.711); called by muse, mutect2
- CA7 | c.574C>T p.H192Y | Missense Mutation (SNP) | VAF 133/871 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CABP1 | c.668G>A p.R223Q (on ENST00000316803 / NM_001033677.1; = p.R20Q on NM_004276.5) | Missense Mutation (SNP) | VAF 297/709 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); called by muse, varscan2
- CACNG3 | c.409A>T p.S137C | Missense Mutation (SNP) | VAF 298/649 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, varscan2
- CALR | c.129G>T p.K43N | Missense Mutation (SNP) | VAF 84/457 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- CAMSAP3 | c.2690A>G p.D897G | Missense Mutation (SNP) | VAF 476/990 reads (48%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- CAPN12 | c.1217del p.G406Afs*33 | Frame Shift Del (DEL) | VAF 82/476 reads (17%) | called by mutect2, pindel, varscan2
- CARMIL2 | c.678C>A p.D226E | Missense Mutation (SNP) | VAF 274/615 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- CASP2 | c.898T>G p.F300V | Missense Mutation (SNP) | VAF 295/670 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CASP9 | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 452/754 reads (60%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCDC114 | c.1852T>C p.S618P | Missense Mutation (SNP) | VAF 36/1156 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); called by muse, mutect2
- CCDC141 | c.1906del p.E636Rfs*5 | Frame Shift Del (DEL) | VAF 53/199 reads (27%) | called by pindel, varscan2
- CCDC168 | c.17856del p.K5952Nfs*2 | Frame Shift Del (DEL) | VAF 156/286 reads (55%) | called by mutect2, pindel, varscan2
- CCDC168 | c.13675G>A p.E4559K | Missense Mutation (SNP) | VAF 172/514 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- CCDC168 | c.9262_9265del p.L3088Vfs*18 | Frame Shift Del (DEL) | VAF 98/308 reads (32%) | called by mutect2, varscan2
- CCDC168 | c.5485C>A p.Q1829K | Missense Mutation (SNP) | VAF 231/380 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- CCDC74A | c.404T>C p.L135P | Missense Mutation (SNP) | VAF 297/1515 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- CCDC8 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 534/1158 reads (46%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.001); called by muse, varscan2
- CCP110 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 253/479 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CCR1 | c.346G>T p.G116C | Missense Mutation (SNP) | VAF 251/253 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD58 | c.174dup p.Q59Tfs*4 | Frame Shift Ins (INS) | VAF 126/346 reads (36%) | called by pindel, varscan2
- CD63 | c.331-2A>G p.X111_splice | Splice Site (SNP) | VAF 289/293 reads (99%) | called by muse, mutect2, varscan2
- CD81 | c.634G>A p.V212I | Missense Mutation (SNP) | VAF 354/1059 reads (33%) | SIFT tolerated (1); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- CDH9 | c.782T>C p.V261A | Missense Mutation (SNP) | VAF 90/462 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- CDK12 | c.3810del p.G1271Dfs*23 (on ENST00000447079 / NM_016507.4; = p.G1262Dfs*23 on NM_015083.3) | Frame Shift Del (DEL) | VAF 171/358 reads (48%) | called by pindel, varscan2
- CDV3 | c.272_273del p.K91Rfs*3 | Frame Shift Del (DEL) | VAF 231/408 reads (57%) | called by mutect2, pindel, varscan2
- CEACAM6 | c.937G>T p.V313F | Missense Mutation (SNP) | VAF 206/499 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CENPH | c.314+1G>A p.X105_splice | Splice Site (SNP) | VAF 43/154 reads (28%) | called by muse, mutect2, varscan2
- CENPI | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 267/582 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.077); called by muse, varscan2
- CEP131 | c.1045C>A p.L349M | Missense Mutation (SNP) | VAF 125/610 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- CEP63 | c.53del p.L18* | Frame Shift Del (DEL) | VAF 161/278 reads (58%) | called by mutect2, pindel, varscan2
- CFL1 | c.74C>T p.T25M | Missense Mutation (SNP) | VAF 302/602 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- CHD9 | c.2280del p.F760Lfs*16 | Frame Shift Del (DEL) | VAF 38/226 reads (17%) | called by pindel, varscan2
- CHERP | c.1676G>T p.R559L | Missense Mutation (SNP) | VAF 558/1155 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CHMP1B | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 378/771 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- CHRNA4 | c.767T>G p.L256R | Missense Mutation (SNP) | VAF 463/777 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHRNB1 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 495/496 reads (100%) | called by muse, varscan2
- CHRNE | c.1261C>A p.R421S | Missense Mutation (SNP) | VAF 167/668 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- CHSY3 | c.797T>C p.I266T | Missense Mutation (SNP) | VAF 69/586 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, varscan2
- CLCN3 | c.931del p.R311Gfs*14 | Frame Shift Del (DEL) | VAF 23/123 reads (19%) | called by mutect2, pindel, varscan2
- CLDN11 | c.512G>A p.G171D | Missense Mutation (SNP) | VAF 255/878 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLIP1 | c.464G>A p.S155N | Missense Mutation (SNP) | VAF 159/891 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CLP1 | c.457G>T p.G153C | Missense Mutation (SNP) | VAF 412/882 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLPTM1L | c.616del p.T206Pfs*17 | Frame Shift Del (DEL) | VAF 222/559 reads (40%) | called by mutect2, pindel, varscan2
1,093 further variants in this file (547 protein-altering or splice-affecting, 371 silent, 175 other) are not listed here.
